Somatic mutation profile of tumor specimen TCGA-GF-A3OT-06A (aliquot TCGA-GF-A3OT-06A-23D-A23B-08) from TCGA case TCGA-GF-A3OT, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 58.5 years (21,359 days).
Specimen TCGA-GF-A3OT-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3f4edaee-7ef7-48a1-8e22-f2184e75ef65.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-GF-A3OT-10A (Blood Derived Normal), aliquot TCGA-GF-A3OT-10A-01D-A23B-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/039bf595-df80-4ad8-83ce-6a0717f4c25b

The open-access MAF lists 661 somatic variants for this specimen: 421 protein-altering or splice-affecting, 222 silent, 18 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 371, Silent 222, Nonsense Mutation 32, Splice Region 7, RNA 7, Splice Site 6, 5'UTR 4, Intron 4, Frame Shift Del 3, 5'Flank 3, Translation Start Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EIF1AX | c.28A>G p.K10E | Missense Mutation (SNP) | VAF 32/107 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.475); catalogued as rs757280897, COSV63309287; called by muse, mutect2, varscan2
- FLNA | c.1065G>A p.K355= | Splice Region (SNP) | VAF 22/70 reads (31%) | catalogued as rs1557179325, COSV61038540; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MYO18B | c.3052C>T p.P1018S | Missense Mutation (SNP) | VAF 11/76 reads (14%) | hotspot (GDC flag); SIFT tolerated (0.67); PolyPhen benign (0.344); catalogued as COSV100123667, COSV59127388; called by muse, mutect2, varscan2
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 82/204 reads (40%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 16/71 reads (23%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABAT | c.152C>T p.P51L | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51620926, COSV51624320; called by muse, mutect2, varscan2
- ABCA12 | c.6775C>T p.L2259F (on ENST00000272895 / NM_173076.3; = p.L1941F on NM_015657.3) | Missense Mutation (SNP) | VAF 41/161 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1021189736, COSV55951149, COSV99077959; called by muse, mutect2, varscan2
- ABCC2 | c.794C>T p.S265F | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.41); PolyPhen benign (0.178); catalogued as rs771901947, COSV100965577; called by muse, mutect2
- ABCC3 | c.3457G>A p.E1153K | Missense Mutation (SNP) | VAF 62/262 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53318006; called by muse, mutect2, varscan2
- ABLIM2 | c.1471G>A p.D491N (on ENST00000341937 / NM_001130084.2; = p.D440N on NM_032432.5) | Missense Mutation (SNP) | VAF 36/159 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs765886161, COSV56400904; called by muse, mutect2, varscan2
- ACSM4 | c.553C>T p.L185F | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV68066962; called by muse, mutect2, varscan2
- ACSM6 | c.842G>A p.G281E | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.326); catalogued as COSV58977705; called by muse, mutect2, varscan2
- ADAM18 | c.1618C>T p.P540S | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.115); catalogued as rs767965639, COSV55844558; called by muse, mutect2, varscan2
- ADAMTS9 | c.2199A>C p.L733F | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55776332; called by muse, mutect2, varscan2
- ADCY1 | c.1249G>A p.D417N | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52031045; called by muse, mutect2, varscan2
- ADGRG4 | c.5240C>T p.P1747L | Missense Mutation (SNP) | VAF 51/157 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV54950973; called by muse, mutect2, varscan2
- ADGRL2 | c.1388C>T p.P463L | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT deleterious (0.05); PolyPhen benign (0.012); catalogued as rs757313514, COSV54655759; called by muse, mutect2, varscan2
- ADGRL3 | c.905G>A p.R302Q (on ENST00000506720 / NM_001322402.2; = p.R234Q on NM_015236.6) | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as rs1345765166, COSV72266433; called by muse, mutect2, varscan2
- ADH1A | c.112C>T p.R38C | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs1039874400, COSV52924296; called by muse, mutect2, varscan2
- ADNP | c.1867C>T p.L623F | Missense Mutation (SNP) | VAF 84/339 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.031); catalogued as COSV100823693, COSV62424619; called by muse, mutect2, varscan2
- ADNP2 | c.1880C>T p.P627L | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); catalogued as COSV51536612; called by muse, mutect2, varscan2
- ADRA1A | c.103G>A p.G35S | Missense Mutation (SNP) | VAF 70/376 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV52357880; called by muse, mutect2, varscan2
- ALK | c.1673G>T p.G558V | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101201160, COSV66559733; called by muse, mutect2, varscan2
- ANK2 | c.205C>T p.H69Y | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52149111; called by muse, mutect2, varscan2
- ANK3 | c.8948C>T p.S2983L | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs747386150, COSV55047208; called by muse, mutect2, varscan2
- ANKFN1 | c.1043C>T p.S348L | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.85); catalogued as rs1448778167, COSV59442211; called by muse, mutect2, varscan2
- ANKRD12 | c.5006C>T p.P1669L | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.015); catalogued as COSV50820002; called by muse, mutect2, varscan2
- ANKRD24 | c.1914G>A p.M638I | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.003); catalogued as rs776282831, COSV53668317; called by muse, mutect2, varscan2
- ANKRD24 | c.3103G>A p.E1035K | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.757); catalogued as COSV53668352; called by muse, mutect2, varscan2
- AP000311.1 | c.307C>A p.P103T | Missense Mutation (SNP) | VAF 21/108 reads (19%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.632); catalogued as COSV51708021; called by muse, mutect2, varscan2
- APLP2 | c.2275G>A p.E759K | Missense Mutation (SNP) | VAF 30/113 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1486252868, COSV53839270; called by muse, mutect2, varscan2
- APOBEC3A | c.593G>A p.G198E | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as COSV99970309; called by muse, mutect2, varscan2
- APOBEC3F | c.131C>T p.P44L | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.098); catalogued as COSV100415122; called by muse, mutect2, varscan2
- ARHGEF40 | c.4315C>T p.P1439S | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.829); catalogued as rs770811232, COSV100070119; called by muse, mutect2, varscan2
- ARHGEF40 | c.4316C>T p.P1439L | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.878); catalogued as rs774167354, COSV100070122; called by muse, mutect2, varscan2
- ARSH | c.1432G>A p.D478N | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.077); catalogued as rs759497002, COSV66962565; called by muse, mutect2, varscan2
- ASPG | c.905G>A p.G302E | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV71933600; called by muse, mutect2, varscan2
- ATF7IP2 | c.1229A>G p.N410S | Missense Mutation (SNP) | VAF 33/121 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.385); catalogued as COSV61092418; called by muse, mutect2, varscan2
- ATP2B4 | c.3590C>T p.S1197F | Missense Mutation (SNP) | VAF 42/72 reads (58%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.047); catalogued as COSV58174835; called by muse, mutect2, varscan2
- BBS9 | c.1421T>C p.F474S | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV54158727; called by muse, mutect2, varscan2
- BEST2 | c.907G>A p.D303N | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV50359678; called by muse, mutect2, varscan2
- BEST3 | c.1939G>A p.E647K | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.017); catalogued as COSV58299331; called by muse, mutect2, varscan2
- BRD1 | c.2351del p.G784Afs*109 (on ENST00000216267 / NM_001349940.1; = p.G784Afs*35 on NM_001304808.3) | Frame Shift Del (DEL) | VAF 10/56 reads (18%) | catalogued as COSV53456060; called by mutect2, pindel, varscan2
- BRD4 | c.677C>T p.P226L | Missense Mutation (SNP) | VAF 35/181 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.831); catalogued as COSV54583121; called by muse, mutect2, varscan2
- C15orf48 | c.143C>T p.P48L | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.136); catalogued as COSV60223194; called by muse, mutect2
- C1QBP | c.422C>T p.P141L | Missense Mutation (SNP) | VAF 26/99 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.473); catalogued as COSV56709032; called by muse, mutect2, varscan2
- C3orf56 | c.570G>A p.W190* | Nonsense Mutation (SNP) | VAF 13/43 reads (30%) | catalogued as COSV67756040; called by muse, mutect2, varscan2
- C4orf50 | c.441G>A p.M147I (on ENST00000324058; = p.M1379I on NM_001364689.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/117 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.035); catalogued as rs547206177, COSV60687722; called by muse, mutect2, varscan2
- C9orf152 | c.506G>A p.G169E | Missense Mutation (SNP) | VAF 60/229 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV68762713; called by muse, mutect2, varscan2
- CA10 | c.445G>A p.G149R | Missense Mutation (SNP) | VAF 33/186 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.939); catalogued as COSV53340380; called by muse, mutect2, varscan2
- CALCOCO1 | c.1651C>T p.P551S | Missense Mutation (SNP) | VAF 29/121 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV50412025; called by muse, mutect2, varscan2
- CAMKK2 | c.254C>T p.T85I | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.007); catalogued as rs1248158748, COSV61213364; called by muse, mutect2, varscan2
- CASR | c.826C>T p.L276F | Missense Mutation (SNP) | VAF 46/161 reads (29%) | SIFT tolerated (0.37); PolyPhen benign (0.099); catalogued as COSV56134850; called by muse, mutect2, varscan2
- CCDC144A | c.241C>T p.L81F | Missense Mutation (SNP) | VAF 51/232 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.047); catalogued as COSV61402638; called by muse, mutect2, varscan2
- CCDC88C | c.3986G>A p.G1329E | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV66234853; called by muse, mutect2, varscan2
- CCN4 | c.446G>A p.G149D | Missense Mutation (SNP) | VAF 16/119 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); catalogued as COSV51529914; called by muse, mutect2, varscan2
- CCNB3 | c.3732G>A p.M1244I | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as COSV52070602, COSV99329263; called by muse, mutect2, varscan2
- CCNE1 | c.812C>T p.P271L | Missense Mutation (SNP) | VAF 33/119 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52903662; called by muse, mutect2, varscan2
- CD1B | c.885G>A p.W295* | Nonsense Mutation (SNP) | VAF 14/69 reads (20%) | catalogued as COSV100939156; called by muse, mutect2, varscan2
- CD1B | c.884G>A p.W295* | Nonsense Mutation (SNP) | VAF 14/69 reads (20%) | catalogued as rs769924792, COSV100939159, COSV63803994; called by muse, mutect2, varscan2
- CDH19 | c.2174G>A p.G725E | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV50955003; called by muse, mutect2, varscan2
- CDKL4 | c.437G>A p.G146E | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV66508591; called by muse, mutect2, varscan2
- CEACAM18 | c.551C>T p.S184F | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.688); catalogued as COSV67282323, COSV67282587; called by muse, mutect2, varscan2
- CEACAM21 | c.398A>G p.Q133R | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT tolerated (0.56); PolyPhen benign (0.242); catalogued as rs1404366573, COSV51813204; called by muse, mutect2, varscan2
- CEBPE | c.10G>A p.G4R | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.068); catalogued as rs545367685, COSV52828784; called by muse, mutect2
- CES4A | c.1022C>T p.S341L | Missense Mutation (SNP) | VAF 36/150 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as COSV58652110; called by muse, mutect2, varscan2
- CHD8 | c.3398G>A p.G1133D (on ENST00000646647 / NM_001170629.2; = p.G854D on NM_020920.4) | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866834770, COSV67869819; called by muse, mutect2
- CHIT1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.253); catalogued as rs201499550, COSV55145532; called by muse, mutect2, varscan2
- CLCA4 | c.463C>T p.H155Y | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55366728; called by muse, mutect2, varscan2
- CLCN1 | c.1065-1G>A p.X355_splice | Splice Site (SNP) | VAF 16/80 reads (20%) | catalogued as rs867830653, COSV58367852; called by muse, mutect2, varscan2
- CLCN1 | c.2120C>G p.S707C | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58367864; called by muse, mutect2
- CLCN6 | c.806C>T p.S269L | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as rs761839015, COSV56738374; called by muse, mutect2, varscan2
- CLCNKB | c.1298G>A p.G433E | Missense Mutation (SNP) | VAF 36/138 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761374224, CM071617, COSV65159818; called by muse, mutect2, varscan2
- CLPS | c.62C>T p.P21L | Missense Mutation (SNP) | VAF 18/152 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV52565954; called by muse, mutect2, varscan2
- CNGB3 | c.590T>G p.L197* | Nonsense Mutation (SNP) | VAF 84/210 reads (40%) | catalogued as COSV60685790; called by muse, mutect2, varscan2
- COL11A1 | c.4556G>A p.G1519E | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62174945, COSV62188495; called by muse, mutect2, varscan2
- COL1A2 | c.2169T>A p.N723K | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.026); catalogued as COSV51953950; called by muse, mutect2, varscan2
- COL21A1 | c.2048G>A p.G683E | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55155390; called by muse, mutect2
- COL4A5 | c.1510C>T p.P504S | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as rs1569493681, COSV60357134; called by muse, mutect2, varscan2
- COL5A3 | c.4307G>A p.G1436E | Missense Mutation (SNP) | VAF 45/208 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53407142; called by muse, mutect2, varscan2
- CPA3 | c.709C>T p.R237C | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199600994, COSV56044010; called by muse, mutect2, varscan2
- CRYBG2 | c.414G>A p.M138I | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.072); catalogued as COSV57484168; called by muse, mutect2, varscan2
- CSMD1 | c.9977G>A p.G3326E (on ENST00000520002; = p.G3325E on NM_033225.6) | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV59286808; called by muse, mutect2, varscan2
- CSMD2 | c.9859G>A p.G3287R | Missense Mutation (SNP) | VAF 90/211 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1353077473, COSV53886168; called by muse, mutect2, varscan2
- CSMD2 | c.5987G>A p.W1996* | Nonsense Mutation (SNP) | VAF 11/31 reads (35%) | catalogued as COSV53886189; called by muse, mutect2, varscan2
- CSMD3 | c.10186G>A p.D3396N (on ENST00000297405 / NM_001363185.1; = p.D3227N on NM_052900.3) | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (1); PolyPhen probably damaging (0.988); catalogued as COSV52116914; called by muse, mutect2, varscan2
- CSMD3 | c.2434C>T p.Q812* (on ENST00000297405 / NM_001363185.1; = p.Q708* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 19/132 reads (14%) | catalogued as COSV52116928; called by muse, mutect2, varscan2
- CSRNP3 | c.1295C>T p.S432F | Missense Mutation (SNP) | VAF 49/175 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV58775740; called by muse, mutect2, varscan2
- CTCFL | c.767C>T p.T256I | Missense Mutation (SNP) | VAF 46/195 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.048); catalogued as COSV54771485; called by muse, mutect2, varscan2
- CTNNA3 | c.1006C>T p.R336C | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs375721994; called by muse, mutect2, varscan2
- CYP3A4 | c.653C>T p.P218L | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.099); catalogued as CM016156, COSV60501165; called by muse, mutect2, varscan2
- CYP4F8 | c.439C>T p.H147Y | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs745629596, COSV57853335; called by muse, mutect2, varscan2
- DCLK3 | c.1832C>T p.P611L | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.244); catalogued as COSV69362453; called by muse, mutect2, varscan2
- DENND3 | c.1564C>T p.H522Y | Missense Mutation (SNP) | VAF 41/216 reads (19%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.759); catalogued as COSV52801179; called by muse, mutect2, varscan2
- DGAT2 | c.652C>T p.R218W | Missense Mutation (SNP) | VAF 32/177 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.94); catalogued as rs528376420, COSV57175477; called by muse, mutect2, varscan2
- DHODH | c.679G>A p.A227T | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV54661387; called by muse, mutect2
- DHX29 | c.2002C>T p.R668* | Nonsense Mutation (SNP) | VAF 23/125 reads (18%) | catalogued as rs751399112, COSV52416920; called by muse, mutect2, varscan2
- DHX38 | c.701C>T p.S234F | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.312); catalogued as COSV51696740; called by muse, mutect2, varscan2
- DICER1 | c.2021C>T p.P674L | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.153); catalogued as COSV58616338; called by muse, mutect2, varscan2
- DMBT1 | c.5330G>A p.R1777K (on ENST00000338354 / NM_001377530.1; = p.R1020K on NM_004406.3) | Missense Mutation (SNP) | VAF 106/416 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.135); catalogued as rs1199016220, COSV57536627; called by muse, mutect2, varscan2
- DMC1 | c.385C>T p.R129C | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201014421, COSV53258054; called by muse, mutect2, varscan2
- DMXL2 | c.595C>T p.P199S | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT tolerated (0.68); PolyPhen benign (0.001); catalogued as COSV51841749; called by muse, mutect2, varscan2
- DNAH5 | c.11233C>T p.H3745Y | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.028); catalogued as COSV54208394; called by muse, mutect2, varscan2
- DNAH5 | c.6296T>C p.I2099T | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as COSV54208404; called by muse, mutect2, varscan2
- DNAH8 | c.4013G>A p.R1338K | Missense Mutation (SNP) | VAF 31/105 reads (30%) | SIFT tolerated (0.97); PolyPhen benign (0.003); catalogued as COSV104403129, COSV59429786; called by muse, mutect2, varscan2
- DNAJC13 | c.5687T>C p.L1896S | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.822); catalogued as COSV53446682; called by muse, mutect2, varscan2
- DPP3 | c.475C>T p.R159* | Nonsense Mutation (SNP) | VAF 24/98 reads (24%) | catalogued as rs749706093, COSV64756139; called by muse, mutect2, varscan2
- DSCAML1 | c.5348G>A p.R1783Q (on ENST00000321322; = p.R1723Q on NM_020693.4) | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1248409383, COSV58383541; called by muse, mutect2
- DSEL | c.1489G>A p.E497K | Missense Mutation (SNP) | VAF 24/124 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59489857; called by muse, varscan2
- DYSF | c.5575C>T p.R1859C | Missense Mutation (SNP) | VAF 31/140 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.075); catalogued as rs867929621, COSV50274244; called by muse, mutect2, varscan2
- EBF2 | c.1688G>A p.G563E | Missense Mutation (SNP) | VAF 28/202 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.197); catalogued as rs776859966, COSV68776429; called by muse, mutect2, varscan2
- ECHS1 | c.248G>A p.G83E | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs749433804, COSV63906600; called by muse, mutect2, varscan2
- EHHADH | c.2153C>T p.S718F | Missense Mutation (SNP) | VAF 33/114 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as rs140662313, COSV51628141; called by muse, mutect2, varscan2
- ENPP5 | c.893A>C p.K298T | Missense Mutation (SNP) | VAF 40/182 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as COSV57908223, COSV57909454; called by muse, mutect2, varscan2
- ENTPD1 | c.719G>A p.R240H | Missense Mutation (SNP) | VAF 29/149 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.595); catalogued as rs375311388; called by muse, mutect2, varscan2
- ERBB3 | c.872C>T p.P291L | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767016749, COSV57248002; called by muse, mutect2, varscan2
- ETV7 | c.883G>A p.E295K | Missense Mutation (SNP) | VAF 83/393 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60316207; called by muse, mutect2, varscan2
- EVX2 | c.128C>T p.S43L | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.06); catalogued as COSV57962641; called by muse, mutect2
- F13B | c.158A>G p.K53R | Missense Mutation (SNP) | VAF 49/205 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.023); catalogued as COSV66372599; called by muse, mutect2, varscan2
- FAM151B | c.713C>T p.S238F | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.837); catalogued as COSV56471944; called by muse, mutect2, varscan2
- FAM153A | c.175G>A p.E59K | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT tolerated, low confidence (0.52); PolyPhen possibly damaging (0.502); catalogued as rs757261343, COSV100646953; called by muse, mutect2, varscan2
- FAM171A1 | c.1775G>A p.G592E | Missense Mutation (SNP) | VAF 40/151 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65313905; called by muse, mutect2, varscan2
- FAM47C | c.74C>T p.P25L | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.42); PolyPhen benign (0.006); catalogued as COSV63724273; called by muse, mutect2, varscan2
- FAM83B | c.2989C>T p.R997* | Nonsense Mutation (SNP) | VAF 21/68 reads (31%) | catalogued as rs367914924; called by muse, mutect2, varscan2
- FAT2 | c.7534C>T p.P2512S | Missense Mutation (SNP) | VAF 42/195 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.995); catalogued as COSV55814718; called by muse, mutect2, varscan2
- FAT3 | c.1523C>T p.T508I | Missense Mutation (SNP) | VAF 26/124 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as rs1482220473, COSV53082949; called by muse, mutect2, varscan2
- FAT3 | c.8363C>T p.P2788L | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0.075); catalogued as rs762719647, COSV53082968; called by muse, mutect2, varscan2
- FBXW10 | c.2236C>T p.P746S | Missense Mutation (SNP) | VAF 49/218 reads (22%) | SIFT tolerated (0.79); PolyPhen benign (0.01); catalogued as COSV57315303; called by muse, mutect2, varscan2
- FBXW7 | c.358C>T p.Q120* | Nonsense Mutation (SNP) | VAF 13/70 reads (19%) | catalogued as COSV55898137; called by muse, mutect2, varscan2
- FRAS1 | c.5782C>T p.H1928Y | Missense Mutation (SNP) | VAF 42/250 reads (17%) | SIFT tolerated (0.42); PolyPhen benign (0.258); catalogued as COSV53594017; called by muse, mutect2, varscan2
- GABBR1 | c.2022T>A p.F674L | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV63541208; called by muse, mutect2, varscan2
- GABPA | c.272C>G p.T91S | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV100702463, COSV61395601; called by muse, mutect2, varscan2
- GABRA4 | c.817C>T p.L273F | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51921709, COSV51923536; called by muse, mutect2, varscan2
- GABRG2 | c.1015G>A p.D339N (on ENST00000361925 / NM_001375343.1; = p.D299N on NM_000816.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 41/143 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62715864; called by muse, mutect2, varscan2
- GBP7 | c.1453G>A p.E485K | Missense Mutation (SNP) | VAF 53/116 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.127); catalogued as rs763982688, COSV54008401; called by muse, varscan2
- GBP7 | c.1368A>C p.A456= | Splice Region (SNP) | VAF 21/86 reads (24%) | catalogued as COSV54008408; called by muse, varscan2
- GGT5 | c.1301G>A p.R434Q | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.701); catalogued as rs759124656, COSV54068737; called by muse, mutect2, varscan2
- GLRA1 | c.57C>T p.S19= | Splice Region (SNP) | VAF 11/56 reads (20%) | catalogued as rs1003664889, COSV51008179; called by muse, mutect2, varscan2
- GOT1 | c.1027G>A p.E343K | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as COSV65147109; called by muse, mutect2, varscan2
- GOT1 | c.398C>T p.P133L | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0.129); catalogued as COSV100981704, COSV65147115; called by muse, mutect2, varscan2
- GPAA1 | c.416C>T p.A139V | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.721); catalogued as COSV100283983; called by muse, mutect2, varscan2
- GPC4 | c.1060C>T p.R354C | Missense Mutation (SNP) | VAF 89/278 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63697091; called by muse, mutect2, varscan2
- GRIN2B | c.440G>A p.G147D | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV74204987; called by muse, mutect2
- GYS2 | c.1192G>A p.E398K | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.992); catalogued as rs781135571, COSV53921073; called by muse, mutect2, varscan2
- GYS2 | c.1157G>A p.R386Q | Missense Mutation (SNP) | VAF 34/148 reads (23%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.995); catalogued as rs751135925, COSV53921084; called by muse, mutect2, varscan2
- HCLS1 | c.1262G>T p.G421V | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.446); catalogued as COSV57522377; called by muse, mutect2, varscan2
- HECW2 | c.1619C>T p.S540F | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.191); catalogued as COSV53648718, COSV53651582; called by muse, mutect2, varscan2
- HHLA2 | c.350G>A p.G117E | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV63315449; called by muse, mutect2, varscan2
- HIVEP2 | c.2525C>T p.S842L | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV50006211; called by muse, mutect2, varscan2
- HIVEP3 | c.5920G>A p.E1974K | Missense Mutation (SNP) | VAF 46/119 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.651); catalogued as COSV56010679; called by muse, mutect2, varscan2
- HJV | c.406C>T p.P136S (on ENST00000336751 / NM_213653.4; = p.P23S on NM_145277.5) | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0.05); PolyPhen benign (0.006); catalogued as rs1553769716, COSV60951373; called by muse, mutect2, varscan2
- HSPA2 | c.1798A>G p.K600E | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.068); catalogued as COSV55968939; called by muse, mutect2, varscan2
- HYDIN | c.950G>A p.R317Q | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.652); catalogued as rs200044160; called by muse, varscan2
- IGHV1OR21-1 | c.4G>A p.D2N | Missense Mutation (SNP) | VAF 42/544 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.83); catalogued as rs759271623; called by muse, mutect2
- IL20RB | c.765G>A p.W255* | Nonsense Mutation (SNP) | VAF 74/338 reads (22%) | catalogued as COSV59046927; called by muse, mutect2, varscan2
- IMPG2 | c.1669T>G p.S557A | Missense Mutation (SNP) | VAF 42/174 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV51974526; called by muse, mutect2, varscan2
- INPP5D | c.424G>A p.E142K (on ENST00000445964 / NM_001017915.3; = p.E141K on NM_005541.5) | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.185); catalogued as COSV100856893, COSV64035749; called by muse, mutect2
- INTS14 | c.1135C>T p.P379S (on ENST00000313182 / NM_001366360.2; = p.P300S on NM_001136043.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as COSV57525904; called by muse, mutect2, varscan2
- IP6K3 | c.766G>A p.V256I | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.416); catalogued as rs374728443; called by muse, mutect2, varscan2
- IPO5 | c.1315C>T p.H439Y | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as rs769611200, COSV55152521; called by muse, mutect2, varscan2
- IRAK2 | c.1531C>T p.P511S | Missense Mutation (SNP) | VAF 37/159 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.01); catalogued as COSV56529218; called by muse, mutect2, varscan2
- ITGA2B | c.3112G>A p.G1038R | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as COSV52231450; called by muse, mutect2, varscan2
- KANSL2 | c.928C>T p.R310C | Missense Mutation (SNP) | VAF 25/157 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.288); catalogued as rs1041614958, COSV63479469; called by muse, mutect2, varscan2
- KAT2B | c.668A>T p.Q223L | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.568); catalogued as COSV55427192; called by muse, mutect2, varscan2
- KCNH7 | c.1096C>T p.R366* | Nonsense Mutation (SNP) | VAF 65/201 reads (32%) | catalogued as rs1232302531, COSV59788219; called by muse, mutect2, varscan2
- KCNJ6 | c.137G>A p.R46Q | Missense Mutation (SNP) | VAF 32/131 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs546019911, COSV55710387; called by muse, mutect2, varscan2
- KCNK10 | c.1125G>A p.M375I | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.593); catalogued as COSV56640333; called by muse, mutect2, varscan2
- KCNK5 | c.1015C>T p.P339S | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs1370862947, COSV63988648; called by muse, mutect2, varscan2
- KCNQ5 | c.1912G>A p.A638T | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0.07); catalogued as COSV59651747; called by muse, mutect2, varscan2
- KDR | c.3637C>T p.H1213Y | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.974); catalogued as rs867819358, COSV55759130; called by muse, mutect2, varscan2
- KDR | c.1525G>A p.G509R | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.063); catalogued as rs1253895551, COSV55759142; called by muse, mutect2, varscan2
- KIAA0319 | c.2063C>T p.T688I | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.067); catalogued as COSV65496792; called by muse, mutect2, varscan2
- KIAA1586 | c.542C>T p.S181F | Missense Mutation (SNP) | VAF 31/137 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV66056197; called by muse, mutect2, varscan2
- KIAA1841 | c.414G>C p.M138I | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs1183745838, COSV54373094; called by muse, mutect2, varscan2
- KIF1C | c.3291G>T p.K1097N | Missense Mutation (SNP) | VAF 25/107 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.497); catalogued as COSV100296891, COSV57903227; called by muse, mutect2, varscan2
- KIF3C | c.2105C>T p.P702L | Missense Mutation (SNP) | VAF 36/126 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0.196); catalogued as COSV99267137; called by muse, mutect2, varscan2
- KIF3C | c.2104C>T p.P702S | Missense Mutation (SNP) | VAF 37/129 reads (29%) | SIFT tolerated (0.37); PolyPhen benign (0.037); catalogued as COSV99267139; called by muse, mutect2, varscan2
- KLKB1 | c.1055C>T p.S352F | Missense Mutation (SNP) | VAF 36/161 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52994273; called by muse, mutect2, varscan2
- KMT2C | c.742A>T p.T248S | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.014); catalogued as COSV51357119; called by muse, mutect2, varscan2
- KNL1 | c.1113T>G p.N371K (on ENST00000346991 / NM_170589.5; = p.N345K on NM_144508.5) | Missense Mutation (SNP) | VAF 23/102 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as COSV61151953; called by muse, mutect2, varscan2
- KRT73 | c.1576G>A p.G526R | Missense Mutation (SNP) | VAF 43/182 reads (24%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.467); catalogued as COSV59838149; called by muse, mutect2, varscan2
- KRT73 | c.1072C>T p.Q358* | Nonsense Mutation (SNP) | VAF 22/120 reads (18%) | catalogued as COSV59838155; called by muse, mutect2, varscan2
- LAMA3 | c.8043G>A p.S2681= (on ENST00000313654 / NM_198129.4; = p.S1072= on NM_000227.6) | Splice Region (SNP) | VAF 14/54 reads (26%) | catalogued as rs1002717654, COSV52530712; called by muse, mutect2, varscan2
- LATS1 | c.804G>A p.W268* | Nonsense Mutation (SNP) | VAF 58/209 reads (28%) | catalogued as COSV53587011; called by muse, mutect2, varscan2
- LDLRAD4 | c.284C>T p.S95F | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV63334407; called by muse, mutect2, varscan2
- LECT2 | c.274C>T p.R92* | Nonsense Mutation (SNP) | VAF 17/60 reads (28%) | catalogued as rs138618187; called by muse, mutect2, varscan2
- LEFTY1 | c.856C>T p.P286S | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV55282393; called by muse, mutect2, varscan2
- LHCGR | c.655C>T p.R219C | Missense Mutation (SNP) | VAF 34/162 reads (21%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.809); catalogued as rs149917479, COSV54297069; called by muse, mutect2, varscan2
- LMAN1 | c.812G>A p.G271E | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.012); catalogued as COSV51826053; called by muse, mutect2
- LMO3 | c.207-1G>A p.X69_splice | Splice Site (SNP) | VAF 11/49 reads (22%) | catalogued as COSV53781436; called by muse, mutect2, varscan2
- LNPEP | c.2005C>T p.Q669* | Nonsense Mutation (SNP) | VAF 18/50 reads (36%) | catalogued as COSV51476687; called by muse, mutect2, varscan2
- LRP1B | c.9583C>T p.H3195Y | Missense Mutation (SNP) | VAF 31/107 reads (29%) | SIFT tolerated (1); PolyPhen probably damaging (0.986); catalogued as COSV101253763, COSV67191721; called by muse, mutect2, varscan2
- LRRC30 | c.481G>A p.D161N | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.723); catalogued as rs746658153, COSV67301387; called by muse, mutect2, varscan2
- LTBP1 | c.3082G>A p.G1028R (on ENST00000404816 / NM_206943.4; = p.G702R on NM_000627.4) | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63181471; called by muse, mutect2, varscan2
- LUC7L3 | c.880C>T p.R294C | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as rs758120330, COSV53585794; called by muse, mutect2, varscan2
- LVRN | c.2084C>T p.S695F | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as rs1224415079, COSV63496395; called by muse, mutect2, varscan2
- MACF1 | c.4100C>T p.S1367F | Missense Mutation (SNP) | VAF 31/149 reads (21%) | catalogued as rs1297993169, COSV100483046; called by muse, mutect2, varscan2
- MAGEB16 | c.277G>A p.E93K | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.28); PolyPhen benign (0.26); catalogued as COSV67873616; called by muse, mutect2, varscan2
- MALT1 | c.1222G>A p.G408R | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100618616; called by muse, mutect2
- MAP3K4 | c.2602A>T p.T868S | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100815111; called by muse, mutect2, varscan2
- MAP3K4 | c.2603C>T p.T868I | Missense Mutation (SNP) | VAF 23/107 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.037); catalogued as COSV100815113; called by muse, mutect2, varscan2
- MAPK6 | c.1195C>T p.R399* | Nonsense Mutation (SNP) | VAF 30/110 reads (27%) | catalogued as COSV55931910; called by muse, mutect2, varscan2
- MARCO | c.1054G>A p.G352R | Missense Mutation (SNP) | VAF 45/201 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1200960269, COSV59052400; called by muse, mutect2, varscan2
- MARK4 | c.247C>T p.R83W | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1013318216, COSV53462070; called by muse, mutect2, varscan2
- MB | c.424G>A p.D142N | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as COSV63093997; called by muse, mutect2, varscan2
- MCM9 | c.577C>T p.P193S | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.436); catalogued as COSV60163524; called by muse, mutect2, varscan2
- MEFV | c.2167G>A p.D723N | Missense Mutation (SNP) | VAF 32/140 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.954); catalogued as COSV54819077, COSV54825429; called by muse, mutect2, varscan2
- MERTK | c.1549T>A p.L517M | Missense Mutation (SNP) | VAF 32/145 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.365); catalogued as COSV54925380; called by muse, mutect2, varscan2
- METTL25 | c.1202A>G p.N401S | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.021); catalogued as COSV50257900; called by muse, mutect2, varscan2
- MGAT1 | c.529C>T p.R177C | Missense Mutation (SNP) | VAF 33/112 reads (29%) | PolyPhen probably damaging (0.955); catalogued as rs1300533992, COSV57133166; called by muse, mutect2, varscan2
- MINDY4 | c.976C>A p.P326T | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.45); PolyPhen benign (0.058); catalogued as COSV99518304; called by muse, mutect2, varscan2
- MINDY4 | c.977C>T p.P326L | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.058); catalogued as COSV99518306; called by muse, mutect2, varscan2
- MINK1 | c.2459C>T p.A820V | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV53416954; called by muse, mutect2, varscan2
- MSH5 | c.1189C>T p.P397S | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.289); catalogued as rs1318922901, COSV65208854; called by muse, mutect2, varscan2
- MSH5 | c.2473G>A p.E825K | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.293); catalogued as COSV65172609; called by muse, mutect2, varscan2
- MSH6 | c.464A>G p.K155R | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.01); catalogued as CM144061, COSV52275350; called by muse, mutect2, varscan2
- MSR1 | c.980-1G>A p.X327_splice | Splice Site (SNP) | VAF 34/82 reads (41%) | catalogued as COSV50507478; called by muse, mutect2, varscan2
- MTMR7 | c.312G>A p.V104= | Splice Region (SNP) | VAF 42/120 reads (35%) | catalogued as COSV51663583; called by muse, mutect2, varscan2
- MUC17 | c.8903C>T p.S2968F | Missense Mutation (SNP) | VAF 131/550 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV60281820; called by muse, mutect2, varscan2
- MUC5B | c.13391G>A p.G4464E | Missense Mutation (SNP) | VAF 42/214 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.065); catalogued as COSV71590412; called by muse, mutect2
- MYBPC1 | c.2014G>A p.D672N (on ENST00000550270 / NM_206820.2; = p.D697N on NM_002465.4) | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.768); catalogued as COSV100637877, COSV62251424; called by muse, mutect2, varscan2
- MYH4 | c.5557G>A p.E1853K | Missense Mutation (SNP) | VAF 33/151 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55113596; called by muse, mutect2, varscan2
- MYH8 | c.5488G>A p.E1830K | Missense Mutation (SNP) | VAF 44/205 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.392); catalogued as COSV67960957; called by muse, mutect2, varscan2
- MYO18B | c.2584G>A p.E862K | Missense Mutation (SNP) | VAF 43/177 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.811); catalogued as COSV59127375; called by muse, mutect2, varscan2
- MYOC | c.566G>A p.R189Q | Missense Mutation (SNP) | VAF 71/331 reads (21%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as rs144579767, COSV50675587; called by muse, mutect2, varscan2
- NAALAD2 | c.737G>A p.G246E | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58959253; called by muse, mutect2, varscan2
- NBPF11 | c.1670C>T p.P557L | Missense Mutation (SNP) | VAF 33/295 reads (11%) | SIFT tolerated (1); PolyPhen probably damaging (0.995); catalogued as rs1385079548; called by muse, mutect2, varscan2
- NCAN | c.3845G>A p.R1282Q | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.701); catalogued as rs201487482, COSV53047516; called by muse, mutect2, varscan2
- NDRG3 | c.559G>C p.D187H (on ENST00000349004 / NM_032013.4; = p.D175H on NM_022477.4) | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as COSV62421179; called by muse, mutect2, varscan2
- NFATC4 | c.2449C>T p.P817S | Missense Mutation (SNP) | VAF 38/199 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.103); catalogued as COSV51597373; called by muse, mutect2, varscan2
- NLRP1 | c.638G>A p.G213E | Missense Mutation (SNP) | VAF 34/140 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.122); catalogued as COSV52559815; called by muse, mutect2, varscan2
- NLRP13 | c.1246G>A p.E416K | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs544413027, COSV61619947; called by muse, mutect2, varscan2
- NLRP7 | c.1975C>T p.R659C | Missense Mutation (SNP) | VAF 24/144 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs763112445, COSV60171739; called by muse, mutect2, varscan2
- NLRP8 | c.2434C>T p.L812F | Missense Mutation (SNP) | VAF 59/210 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52584204, COSV52592143; called by muse, mutect2, varscan2
- NMS | c.376C>T p.H126Y | Missense Mutation (SNP) | VAF 38/170 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV65258385; called by muse, varscan2
- NOVA1 | c.1426G>A p.G476R | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57473234; called by muse, mutect2, varscan2
- NRK | c.4416G>A p.M1472I | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.023); catalogued as COSV54591244; called by muse, mutect2, varscan2
- NTF3 | c.169G>A p.E57K | Missense Mutation (SNP) | VAF 25/120 reads (21%) | SIFT tolerated (0.61); PolyPhen benign (0.023); catalogued as rs1418243403, COSV58417280; called by muse, mutect2, varscan2
- NTRK3 | c.2001G>A p.M667I | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.893); catalogued as COSV62297285; called by muse, mutect2, varscan2
- NUP93 | c.2309C>T p.S770L | Missense Mutation (SNP) | VAF 24/135 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0.017); catalogued as rs572483425, COSV57429064; called by muse, mutect2, varscan2
- NUTM1 | c.2935A>G p.T979A | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV59215963; called by muse, mutect2, varscan2
- OLAH | c.677G>A p.G226E (on ENST00000378228 / NM_001039702.3; = p.G279E on NM_018324.3) | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs139895854; called by muse, mutect2, varscan2
- OLR1 | c.706C>T p.Q236* | Nonsense Mutation (SNP) | VAF 33/168 reads (20%) | catalogued as COSV58870953; called by muse, mutect2, varscan2
- OPRPN | c.373C>T p.P125S | Missense Mutation (SNP) | VAF 37/154 reads (24%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.041); catalogued as COSV68192627; called by muse, mutect2, varscan2
- OR10A5 | c.113T>C p.V38A | Missense Mutation (SNP) | VAF 82/320 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV55053377; called by muse, mutect2, varscan2
- OR10J1 | c.797C>G p.T266S | Missense Mutation (SNP) | VAF 65/138 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV101419803, COSV71128289; called by muse, mutect2, varscan2
- OR1L3 | c.154G>A p.D52N | Missense Mutation (SNP) | VAF 41/207 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.038); catalogued as COSV59169292; called by muse, mutect2, varscan2
- OR4A5 | c.646G>A p.G216R | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.254); catalogued as COSV100157337, COSV60521739; called by muse, mutect2, varscan2
- OR4C6 | c.688G>A p.G230R | Missense Mutation (SNP) | VAF 23/135 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.946); catalogued as rs1565078863, COSV58602789; called by muse, mutect2, varscan2
- OR5K4 | c.746C>T p.S249L | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.35); catalogued as COSV61583445; called by muse, mutect2, varscan2
- P3H2 | c.997C>T p.L333F | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV60019062; called by muse, mutect2, varscan2
- PAPPA | c.2078G>A p.W693* | Nonsense Mutation (SNP) | VAF 40/210 reads (19%) | catalogued as COSV60278539; called by muse, mutect2, varscan2
- PAPPA | c.4261A>T p.K1421* | Nonsense Mutation (SNP) | VAF 32/131 reads (24%) | catalogued as COSV60278555; called by muse, mutect2, varscan2
- PARD3B | c.1414C>A p.H472N | Missense Mutation (SNP) | VAF 36/145 reads (25%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV62504598; called by muse, mutect2, varscan2
- PAX6 | c.538C>A p.Q180K | Missense Mutation (SNP) | VAF 19/111 reads (17%) | SIFT tolerated (0.88); PolyPhen benign (0.003); catalogued as CM950910, COSV53792192; called by muse, mutect2, varscan2
- PCDHB1 | c.1036G>A p.E346K | Missense Mutation (SNP) | VAF 38/125 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.432); catalogued as rs1254111938, COSV60629676; called by muse, mutect2, varscan2
- PCDHB15 | c.1936G>A p.D646N | Missense Mutation (SNP) | VAF 17/104 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.739); catalogued as COSV50861661; called by muse, mutect2, varscan2
- PCDHGA3 | c.73G>A p.E25K | Missense Mutation (SNP) | VAF 59/247 reads (24%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.001); catalogued as rs778709344, COSV53909310, COSV99547028; called by muse, mutect2, varscan2
- PCDHGA4 | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 30/123 reads (24%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0.011); catalogued as rs756032397, COSV53909333; called by muse, mutect2, varscan2
- PCDHGB3 | c.1436C>T p.P479L | Missense Mutation (SNP) | VAF 25/144 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.168); catalogued as COSV53909353, COSV54000386; called by muse, mutect2, varscan2
- PCDHGB6 | c.776C>T p.S259F | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.097); catalogued as COSV53909388; called by muse, mutect2, varscan2
- PCLO | c.11458G>A p.E3820K | Missense Mutation (SNP) | VAF 36/110 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61619748; called by muse, mutect2, varscan2
- PCNT | c.5663C>G p.S1888C | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs763406701, COSV64025706; called by muse, mutect2, varscan2
- PCNX1 | c.1631C>T p.P544L | Missense Mutation (SNP) | VAF 43/198 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.074); catalogued as COSV53090425; called by muse, mutect2, varscan2
- PCSK4 | c.2153C>T p.T718I | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV56298490; called by muse, mutect2, varscan2
- PDE10A | c.886C>T p.R296C | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs866168774, COSV63092169; called by muse, mutect2, varscan2
- PDE6C | c.218G>A p.G73E | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV65115003; called by muse, mutect2, varscan2
- PFAS | c.2060C>T p.S687F | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs765947776, COSV58978795; called by muse, mutect2
- PGR | c.1910G>A p.R637Q | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs766277966, COSV54797179; called by muse, mutect2, varscan2
- PHF21B | c.676C>T p.H226Y | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs748056039, COSV57556438; called by muse, mutect2, varscan2
- PIK3AP1 | c.1420G>A p.D474N | Missense Mutation (SNP) | VAF 53/236 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.372); catalogued as COSV59530784; called by muse, mutect2, varscan2
- PITPNA | c.523C>T p.P175S | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.124); catalogued as rs774499211, COSV57932423; called by muse, mutect2, varscan2
- PKD1 | c.3160C>T p.L1054= | Splice Region (SNP) | VAF 6/32 reads (19%) | catalogued as rs1427376432, COSV51911821; called by muse, mutect2, varscan2
- PKD2L1 | c.358G>A p.G120R | Missense Mutation (SNP) | VAF 26/134 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV58394891; called by muse, mutect2, varscan2
- PKHD1L1 | c.1889G>A p.G630E | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as COSV101007256, COSV65738689; called by muse, mutect2, varscan2
- PKHD1L1 | c.5471G>A p.G1824E | Missense Mutation (SNP) | VAF 18/120 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.704); catalogued as COSV65738692; called by muse, mutect2, varscan2
- PLCB2 | c.59G>A p.G20E | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53031264; called by muse, mutect2, varscan2
- PLCB4 | c.2009C>T p.S670L | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.46); catalogued as rs747043641, COSV53793534; called by muse, mutect2, varscan2
- PLCE1 | c.1199G>A p.W400* | Nonsense Mutation (SNP) | VAF 18/72 reads (25%) | catalogued as COSV53339914; called by muse, mutect2, varscan2
- PLCH1 | c.3464A>G p.D1155G (on ENST00000340059 / NM_001130960.2; = p.D1147G on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.86); catalogued as COSV58189226; called by muse, mutect2, varscan2
- PLEKHO1 | c.318+1G>A p.X106_splice | Splice Site (SNP) | VAF 33/81 reads (41%) | catalogued as rs1553820385, COSV50309857; called by muse, mutect2, varscan2
- POLQ | c.2162C>T p.T721I | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.309); catalogued as COSV51747183; called by muse, mutect2, varscan2
- POTEE | c.387G>A p.M129I | Missense Mutation (SNP) | VAF 20/138 reads (14%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.011); catalogued as COSV58225925; called by muse, varscan2
- PPFIA4 | c.1223G>A p.R408Q | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.206); catalogued as rs777237239, COSV55312336; called by muse, mutect2, varscan2
- PPP2R3A | c.2051C>T p.S684F | Missense Mutation (SNP) | VAF 26/117 reads (22%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV53860379; called by muse, mutect2, varscan2
- PPP6R2 | c.1240G>A p.E414K | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs376757157, COSV53290792; called by muse, mutect2, varscan2
- PPRC1 | c.2761C>T p.P921S | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.982); catalogued as COSV53383602; called by muse, mutect2, varscan2
- PRKG1 | c.1957C>T p.P653S | Missense Mutation (SNP) | VAF 30/123 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV64766281, COSV64767194; called by muse, mutect2, varscan2
- PRR12 | c.2231C>T p.A744V (on ENST00000615927; = p.A1565V on NM_020719.3) | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.161); catalogued as COSV69816720; called by muse, mutect2, varscan2
- PRR16 | c.553C>T p.Q185* (on ENST00000407149 / NM_001300783.2; = p.Q162* on NM_016644.2) | Nonsense Mutation (SNP) | VAF 17/82 reads (21%) | catalogued as COSV65395453; called by muse, mutect2, varscan2
- PRSS35 | c.874G>A p.E292K | Missense Mutation (SNP) | VAF 28/103 reads (27%) | SIFT tolerated (0.39); PolyPhen benign (0.255); catalogued as COSV63800216; called by muse, mutect2, varscan2
- PRSS55 | c.816G>A p.W272* | Nonsense Mutation (SNP) | VAF 20/106 reads (19%) | catalogued as COSV60807879; called by muse, mutect2, varscan2
- PTPA | c.383C>T p.P128L (on ENST00000337738 / NM_178001.2; = p.P93L on NM_021131.5) | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.919); catalogued as COSV61234059; called by muse, mutect2, varscan2
- PTPRK | c.4009G>A p.G1337R (on ENST00000368215 / NM_001291984.2; = p.G1338R on NM_002844.4) | Missense Mutation (SNP) | VAF 22/114 reads (19%) | SIFT tolerated (0.54); PolyPhen probably damaging (1); catalogued as rs1421669318, COSV100951710, COSV63892401; called by muse, mutect2, varscan2
- RAF1 | c.343A>C p.N115H | Missense Mutation (SNP) | VAF 36/133 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.863); catalogued as COSV52575529; called by muse, mutect2, varscan2
- RAG2 | c.446G>A p.G149E | Missense Mutation (SNP) | VAF 29/160 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1487032318, COSV57556617; called by muse, mutect2, varscan2
- RASGRF1 | c.1546G>A p.G516R | Missense Mutation (SNP) | VAF 23/115 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.238); catalogued as COSV69177052; called by muse, mutect2, varscan2
- RBBP6 | c.1850C>T p.S617L | Missense Mutation (SNP) | VAF 53/268 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.078); catalogued as COSV60502925; called by muse, mutect2, varscan2
- RBM7 | c.394C>T p.Q132* | Nonsense Mutation (SNP) | VAF 9/64 reads (14%) | catalogued as COSV64955445; called by muse, mutect2, varscan2
- REG3A | c.384G>A p.M128I | Missense Mutation (SNP) | VAF 19/120 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV59408704, COSV59412686; called by muse, mutect2, varscan2
- RERGL | c.433A>T p.N145Y | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV57461118; called by muse, mutect2, varscan2
- RFX6 | c.1574G>A p.R525Q | Missense Mutation (SNP) | VAF 20/111 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.905); catalogued as rs1309978309, COSV60583429; called by muse, mutect2, varscan2
- RHOBTB1 | c.1481G>A p.G494E | Missense Mutation (SNP) | VAF 30/91 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV61957895; called by muse, mutect2, varscan2
- RIPOR2 | c.1022C>T p.S341F | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52418115; called by muse, mutect2, varscan2
- RMND1 | c.212A>G p.N71S | Missense Mutation (SNP) | VAF 73/247 reads (30%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.003); catalogued as COSV60550077; called by muse, mutect2, varscan2
- RNF128 | c.1112G>A p.G371E (on ENST00000255499 / NM_194463.2; = p.G345E on NM_024539.3) | Missense Mutation (SNP) | VAF 50/246 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.66); catalogued as rs749990844, COSV55249478; called by muse, mutect2, varscan2
- RNF17 | c.3611-1G>A p.X1204_splice | Splice Site (SNP) | VAF 7/22 reads (32%) | catalogued as COSV55035305; called by muse, mutect2, varscan2
- RNF20 | c.91A>G p.T31A | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.899); catalogued as COSV66355534; called by muse, mutect2, varscan2
- ROM1 | c.328G>A p.G110S | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.175); catalogued as COSV53881593; called by muse, mutect2, varscan2
- RP1 | c.2303C>T p.S768F | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV55110595, COSV55111673; called by muse, mutect2, varscan2
- RP1 | c.4135G>A p.E1379K | Missense Mutation (SNP) | VAF 14/104 reads (13%) | SIFT tolerated (0.92); PolyPhen benign (0.045); catalogued as COSV55111690; called by muse, mutect2, varscan2
- RPL6 | c.319G>A p.V107I | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.208); catalogued as COSV99176113; called by muse, mutect2, varscan2
- RSF1 | c.481C>T p.L161F | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV57836971; called by muse, mutect2, varscan2
- RUBCN | c.2688T>G p.N896K | Missense Mutation (SNP) | VAF 66/285 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.065); catalogued as COSV56363350; called by muse, mutect2, varscan2
- RWDD4 | c.539G>A p.S180N | Missense Mutation (SNP) | VAF 28/143 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.247); catalogued as COSV58393460; called by muse, mutect2, varscan2
- RYR1 | c.10495C>T p.R3499W | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs147058802; called by muse, mutect2, varscan2
- SACS | c.2816C>T p.S939F | Missense Mutation (SNP) | VAF 21/115 reads (18%) | SIFT tolerated (0.43); PolyPhen benign (0.017); catalogued as rs747773669, COSV66535662; called by muse, mutect2, varscan2
- SAMD7 | c.1144C>T p.Q382* | Nonsense Mutation (SNP) | VAF 15/73 reads (21%) | catalogued as rs749332091, COSV59417374; called by muse, mutect2, varscan2
- SBDS | c.341T>A p.I114N | Missense Mutation (SNP) | VAF 47/197 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.101); catalogued as COSV55887160; called by muse, mutect2, varscan2
- SCN3A | c.737A>C p.K246T | Missense Mutation (SNP) | VAF 22/184 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.797); catalogued as COSV51803127; called by muse, varscan2
- SCN4A | c.1648A>C p.K550Q | Missense Mutation (SNP) | VAF 54/270 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.67); catalogued as COSV71125822; called by muse, mutect2, varscan2
- SCN5A | c.1733C>T p.P578L | Missense Mutation (SNP) | VAF 31/140 reads (22%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.999); catalogued as COSV61117894; called by muse, mutect2, varscan2
- SEC16A | c.812C>T p.P271L | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as COSV51522518; called by muse, mutect2, varscan2
- SEC24D | c.601C>T p.P201S | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.351); catalogued as COSV54877407; called by muse, mutect2, varscan2
- SET | c.434C>T p.P145L (on ENST00000372692 / NM_001374326.1; = p.P132L on NM_003011.4) | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.548); catalogued as COSV59001280; called by muse, mutect2
- SIDT1 | c.1097G>T p.G366V | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.529); catalogued as COSV53498906; called by muse, mutect2, varscan2
- SIPA1L2 | c.5014C>T p.L1672F | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53384702; called by muse, mutect2, varscan2
- SLC15A1 | c.1174G>A p.G392R | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.049); catalogued as rs779273389, COSV64730275; called by muse, mutect2, varscan2
- SLC1A6 | c.548G>A p.R183K | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.612); catalogued as COSV55668492; called by muse, varscan2
- SLC25A17 | c.86C>T p.P29L | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54350653; called by muse, mutect2, varscan2
- SLC26A5 | c.1432T>G p.S478A | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV59698827; called by muse, mutect2, varscan2
- SLC47A2 | c.533G>T p.G178V | Missense Mutation (SNP) | VAF 47/240 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.086); catalogued as rs894783324, COSV57626688; called by muse, mutect2, varscan2
- SLC6A12 | c.1421G>A p.W474* | Nonsense Mutation (SNP) | VAF 40/170 reads (24%) | catalogued as COSV62884112; called by muse, mutect2, varscan2
- SLC6A7 | c.440C>T p.S147F | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57937112; called by muse, mutect2, varscan2
- SLC7A2 | c.1448C>T p.S483F (on ENST00000494857 / NM_001370338.1; = p.S522F on NM_003046.6) | Missense Mutation (SNP) | VAF 53/180 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.615); catalogued as COSV50248282; called by muse, mutect2, varscan2
- SLC8A1 | c.630G>A p.W210* | Nonsense Mutation (SNP) | VAF 11/57 reads (19%) | catalogued as COSV60472787; called by muse, mutect2, varscan2
- SLCO4C1 | c.671C>T p.S224L | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated (0.32); PolyPhen benign (0.053); catalogued as COSV60513289; called by muse, mutect2, varscan2
- SLIT3 | c.3016G>A p.E1006K | Missense Mutation (SNP) | VAF 19/117 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.343); catalogued as rs142215582; called by muse, mutect2, varscan2
- SLITRK6 | c.571C>T p.R191C | Missense Mutation (SNP) | VAF 40/167 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68389274; called by muse, mutect2, varscan2
- SMARCA4 | c.2644G>A p.E882K | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.881); catalogued as COSV60786460; called by muse, mutect2
- SMARCA4 | c.2933G>A p.R978Q | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1180804356, COSV60786814; called by muse, mutect2, varscan2
- SORL1 | c.5018G>T p.W1673L | Missense Mutation (SNP) | VAF 46/184 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52750367; called by muse, mutect2, varscan2
- SPATA31E1 | c.2686G>A p.G896R | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.775); catalogued as rs1200373982, COSV100350048; called by muse, mutect2, varscan2
- SPATA31E1 | c.2687G>A p.G896E | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.853); catalogued as rs139269965; called by muse, mutect2, varscan2
- SPEF2 | c.2990C>T p.P997L | Missense Mutation (SNP) | VAF 26/127 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV61545012; called by muse, mutect2, varscan2
- SPINK5 | c.1636G>A p.D546N | Missense Mutation (SNP) | VAF 23/118 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV56249822, COSV56264012; called by muse, mutect2, varscan2
- SRCAP | c.5663C>T p.S1888F | Missense Mutation (SNP) | VAF 17/128 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.014); catalogued as COSV99349522; called by muse, mutect2, varscan2
- SRRM2 | c.3095C>T p.S1032F | Missense Mutation (SNP) | VAF 37/150 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV57069329; called by muse, mutect2, varscan2
- STAB2 | c.5350G>A p.D1784N | Missense Mutation (SNP) | VAF 48/179 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs147807697, COSV66335384; called by muse, mutect2, varscan2
- STOML3 | c.316C>T p.L106F | Missense Mutation (SNP) | VAF 26/104 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752862119, COSV65510086; called by muse, mutect2, varscan2
- STOX2 | c.1520G>A p.G507E | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV57849367; called by muse, mutect2, varscan2
- STXBP5L | c.3317G>A p.G1106E | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as COSV56502748; called by muse, mutect2, varscan2
- SUCLG1 | c.517C>T p.P173S | Missense Mutation (SNP) | VAF 24/115 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759846791, COSV67264816; called by muse, mutect2, varscan2
- SV2B | c.113G>A p.G38D | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57698759; called by muse, mutect2, varscan2
- SVEP1 | c.10079C>T p.P3360L | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.394); catalogued as COSV99928523; called by muse, mutect2, varscan2
- SVEP1 | c.10078C>T p.P3360S | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as rs999838067, COSV99928525; called by muse, mutect2, varscan2
- SYT1 | c.1055A>C p.Q352P | Missense Mutation (SNP) | VAF 38/197 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV54036359; called by muse, mutect2, varscan2
- SYT16 | c.1597C>T p.R533* | Nonsense Mutation (SNP) | VAF 11/61 reads (18%) | catalogued as rs1444194985, COSV70855287; called by muse, mutect2, varscan2
- TAT | c.1298G>A p.R433Q | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775488556, CM981892, COSV100587533; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- TBC1D9 | c.3124G>A p.E1042K | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.611); catalogued as rs1164844794, COSV71306990; called by muse, mutect2
- TECTA | c.839C>T p.T280I | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.058); catalogued as COSV50690482; called by muse, mutect2, varscan2
- TECTA | c.2294G>A p.W765* | Nonsense Mutation (SNP) | VAF 20/77 reads (26%) | catalogued as COSV50690511; called by muse, mutect2, varscan2
- TEX9 | c.376G>A p.G126R | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.024); catalogued as rs1424171104, COSV61877160; called by muse, mutect2, varscan2
- TG | c.4559G>A p.G1520D | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.566); catalogued as rs778861204, COSV55067166; called by muse, mutect2, varscan2
- THBS1 | c.1138G>A p.D380N | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.51); catalogued as rs1178564320, CM1110557, COSV52950451; called by muse, mutect2, varscan2
- THBS1 | c.1314G>A p.W438* | Nonsense Mutation (SNP) | VAF 20/106 reads (19%) | catalogued as COSV52950463; called by muse, mutect2, varscan2
- THSD7A | c.2539C>T p.P847S | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.718); catalogued as COSV70261147; called by muse, mutect2, varscan2
- TICRR | c.4196A>C p.Q1399P | Missense Mutation (SNP) | VAF 43/179 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV51538598; called by muse, mutect2, varscan2
- TMEM132A | c.797G>A p.R266Q | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.731); catalogued as rs777345475, COSV50001984, COSV99133888; called by muse, mutect2, varscan2
- TMEM202 | c.81G>A p.R27= | Splice Region (SNP) | VAF 7/28 reads (25%) | catalogued as rs375698920; called by muse, mutect2, varscan2
- TMEM266 | c.80C>T p.S27F | Missense Mutation (SNP) | VAF 37/160 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.189); catalogued as rs891192320, COSV66378746; called by muse, mutect2, varscan2
- TMPRSS15 | c.730C>T p.P244S | Missense Mutation (SNP) | VAF 23/119 reads (19%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.615); catalogued as COSV53034553; called by muse, mutect2, varscan2
- TNFRSF17 | c.532G>A p.E178K | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.154); catalogued as COSV50000140; called by muse, mutect2, varscan2
- TNRC18 | c.484G>A p.G162R | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as COSV68087200; called by muse, mutect2, varscan2
- TOX2 | c.890G>A p.G297E (on ENST00000358131 / NM_001098798.2; = p.G246E on NM_032883.3) | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV57883296; called by muse, mutect2, varscan2
- TPTE2 | c.1214C>T p.S405L (on ENST00000400230 / NM_199254.2; = p.S328L on NM_130785.3) | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.96); catalogued as rs775526037, COSV55017103; called by muse, mutect2
- TRANK1 | c.3163G>A p.E1055K | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.398); catalogued as COSV57143107; called by muse, mutect2, varscan2
- TRIM61 | c.274G>A p.E92K | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.161); catalogued as COSV61418608; called by mutect2, varscan2
- TTN | c.33271G>A p.E11091K (on ENST00000591111; = p.E10164K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 46/126 reads (37%) | PolyPhen possibly damaging (0.654); catalogued as COSV59915955; called by muse, mutect2, varscan2
- UBQLNL | c.265G>A p.G89S | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66493060; called by muse, mutect2, varscan2
- UGT2B11 | c.463C>T p.P155S | Missense Mutation (SNP) | VAF 27/145 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.718); catalogued as rs778246996, COSV71423067; called by muse, mutect2, varscan2
- UGT2B4 | c.193G>A p.D65N | Missense Mutation (SNP) | VAF 40/149 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0.013); catalogued as rs140509960, COSV59315397; called by muse, mutect2, varscan2
- UNC45B | c.1951G>A p.E651K | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.728); catalogued as COSV52092955; called by muse, mutect2, varscan2
- UNC79 | c.6754-1G>A p.X2252_splice (on ENST00000393151 / NM_001346218.2; = p.X2075_splice on NM_020818.5) | Splice Site (SNP) | VAF 25/83 reads (30%) | catalogued as COSV56376810; called by muse, mutect2, varscan2
- UNG | c.275_276dup p.G93Wfs*23 (on ENST00000242576 / NM_080911.3; = p.G84Wfs*23 on NM_003362.4) | Frame Shift Ins (INS) | VAF 12/104 reads (12%) | catalogued as COSV99655447; called by mutect2, pindel, varscan2
- UPF1 | c.10G>A p.E4K | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.079); catalogued as COSV53194211; called by muse, mutect2
- USH2A | c.611G>A p.G204E | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.28); catalogued as COSV56335508; called by muse, mutect2, varscan2
- USP28 | c.2562T>A p.N854K | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV50156461; called by muse, mutect2, varscan2
- USP7 | c.2281A>T p.M761L | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT tolerated (0.34); PolyPhen benign (0.009); catalogued as COSV61213312; called by muse, mutect2
- VIL1 | c.1936G>A p.E646K | Missense Mutation (SNP) | VAF 43/200 reads (22%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.964); catalogued as COSV50285720; called by muse, mutect2, varscan2
- VWF | c.2289G>T p.R763S | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as COSV54613332; called by muse, mutect2, varscan2
- WDHD1 | c.2050C>T p.P684S | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.076); catalogued as rs543826540, COSV62213053; called by muse, mutect2, varscan2
- WHRN | c.1453C>T p.P485S | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.673); catalogued as COSV54327481; called by muse, mutect2, varscan2
- WIPF3 | c.286C>T p.P96S | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.535); catalogued as COSV54206717; called by muse, mutect2, varscan2
- WNT9A | c.980G>A p.G327D | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55293553; called by muse, mutect2, varscan2
- WWTR1 | c.160A>G p.K54E | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.054); catalogued as COSV62290637; called by muse, mutect2, varscan2
- YIPF7 | c.815G>A p.G272E | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV100274380, COSV60657355; called by muse, mutect2, varscan2
- YIPF7 | c.814G>A p.G272R | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV100274382; called by muse, mutect2, varscan2
- ZAN | c.2185G>A p.E729K | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.036); catalogued as COSV100770519, COSV61805947; called by muse, mutect2, varscan2
- ZBTB22 | c.41C>T p.P14L | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs199691306, COSV56467079; called by muse, mutect2
- ZBTB44 | c.1108G>A p.E370K | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.236); catalogued as COSV63536851; called by muse, mutect2
- ZFP91 | c.268G>A p.D90N | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.007); catalogued as COSV60157731; called by muse, mutect2
- ZMAT4 | c.283C>T p.Q95* | Nonsense Mutation (SNP) | VAF 33/166 reads (20%) | catalogued as COSV52691798, COSV52710566; called by muse, mutect2, varscan2
- ZNF239 | c.586C>T p.P196S | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT tolerated (0.41); PolyPhen benign (0.202); catalogued as COSV60018122; called by muse, mutect2
- ZNF343 | c.865C>T p.R289C | Missense Mutation (SNP) | VAF 29/119 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs187274947; called by muse, mutect2, varscan2
- ZNF546 | c.820G>A p.E274K | Missense Mutation (SNP) | VAF 36/158 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV61257330; called by muse, mutect2, varscan2
- ZNF599 | c.402C>G p.N134K | Missense Mutation (SNP) | VAF 26/186 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs745953009, COSV61395629; called by muse, mutect2, varscan2
- ZNF71 | c.680C>T p.S227F | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.598); catalogued as COSV60146843; called by muse, mutect2, varscan2
- ZNF80 | c.187C>T p.L63F | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT tolerated (0.44); PolyPhen benign (0.021); catalogued as COSV57359982; called by muse, mutect2, varscan2
- ZNF831 | c.1312G>A p.G438S | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as COSV64037533; called by muse, mutect2, varscan2
- ZP2 | c.1318G>A p.E440K | Missense Mutation (SNP) | VAF 36/172 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs267604453, COSV54812388; called by muse, mutect2, varscan2
- ZSCAN4 | c.880G>A p.G294R | Missense Mutation (SNP) | VAF 25/111 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.389); catalogued as COSV56591612; called by muse, mutect2, varscan2
- CACNA1C | c.4646_4653del p.P1549Qfs*32 | Frame Shift Del (DEL) | VAF 20/134 reads (15%) | called by mutect2, pindel, varscan2
- CCL4L2 | c.169C>T p.L57F | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- FUT5 | c.913C>T p.H305Y | Missense Mutation (SNP) | VAF 15/103 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- IDO2 | c.616_617del p.R206Tfs*17 (on ENST00000389060; = p.R219Tfs*17 on NM_194294.2) | Frame Shift Del (DEL) | VAF 10/26 reads (38%) | called by mutect2, pindel, varscan2
- IGHV1-3 | c.15G>A p.W5* | Nonsense Mutation (SNP) | VAF 8/48 reads (17%) | called by muse, mutect2, varscan2
- PRAMEF19 | c.1173G>A p.M391I | Missense Mutation (SNP) | VAF 78/639 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.056); called by muse, mutect2
- TRAV23DV6 | c.105T>A p.S35R | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.42); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- TRAV26-2 | c.140C>T p.T47I | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.009); called by muse, varscan2
- TRAV26-2 | c.182C>T p.P61L | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.799); called by muse, varscan2
- ABCA13 | c.6843G>A p.E2281= | Silent (SNP) | VAF 10/32 reads (31%) | catalogued as COSV70026227; called by muse, mutect2, varscan2
- ABCA8 | c.90C>T p.S30= | Silent (SNP) | VAF 17/64 reads (27%) | catalogued as COSV52195791, COSV52207863; called by muse, mutect2, varscan2
- ABCC2 | c.795C>T p.S265= | Silent (SNP) | VAF 9/49 reads (18%) | catalogued as COSV64971355; called by muse, mutect2
- ACAN | c.2001C>T p.S667= | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as COSV61357078, COSV61367685; called by muse, mutect2, varscan2
- ADA2 | c.261C>T p.F87= | Silent (SNP) | VAF 9/57 reads (16%) | catalogued as COSV52830582; called by muse, mutect2, varscan2
- ADAM18 | c.2071C>T p.L691= | Silent (SNP) | VAF 23/104 reads (22%) | catalogued as COSV55844564; called by muse, mutect2, varscan2
- ADAM7 | c.2238C>T p.I746= | Silent (SNP) | VAF 19/137 reads (14%) | catalogued as rs765791653, COSV51535930; called by muse, mutect2, varscan2
- ADGRA2 | c.817C>T p.L273= | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as COSV59441388; called by muse, mutect2, varscan2
- AGPAT1 | c.633C>T p.S211= | Silent (SNP) | VAF 11/70 reads (16%) | catalogued as COSV61247158; called by muse, mutect2, varscan2
- ALOX15B | c.1227C>T p.T409= | Silent (SNP) | VAF 9/36 reads (25%) | catalogued as rs570231718, COSV66479071; called by muse, mutect2, varscan2
- ANGPTL4 | c.393G>A p.E131= | Silent (SNP) | VAF 16/59 reads (27%) | catalogued as rs771012831, COSV56844438; called by muse, mutect2, varscan2
- ANK1 | c.1935G>A p.E645= | Silent (SNP) | VAF 32/199 reads (16%) | catalogued as COSV55875140; called by muse, mutect2, varscan2
- ANK2 | c.10920C>T p.I3640= | Silent (SNP) | VAF 35/180 reads (19%) | catalogued as COSV52149124; called by muse, mutect2, varscan2
- ANK3 | c.3456A>G p.G1152= (on ENST00000280772 / NM_001320874.2; = p.G286= on NM_001149.3) | Silent (SNP) | VAF 25/149 reads (17%) | catalogued as COSV55047218; called by muse, mutect2, varscan2
- ARMC9 | c.591A>G p.T197= | Silent (SNP) | VAF 10/52 reads (19%) | catalogued as COSV63019699; called by muse, mutect2
- ATP12A | c.1854C>T p.V618= | Silent (SNP) | VAF 17/80 reads (21%) | catalogued as COSV54513219; called by muse, mutect2, varscan2
- ATP13A2 | c.762C>T p.D254= | Silent (SNP) | VAF 20/36 reads (56%) | catalogued as COSV58698539; called by muse, mutect2, varscan2
- ATP1A3 | c.2985C>T p.F995= (on ENST00000545399 / NM_001256214.2; = p.F982= on NM_152296.5) | Silent (SNP) | VAF 19/48 reads (40%) | catalogued as rs182309368, COSV57485691; called by muse, mutect2, varscan2
- B3GNT3 | c.696C>T p.H232= | Silent (SNP) | VAF 29/98 reads (30%) | catalogued as COSV57952850; called by muse, mutect2, varscan2
- B3GNT4 | c.483G>T p.V161= | Silent (SNP) | VAF 19/66 reads (29%) | catalogued as COSV57335890; called by muse, mutect2, varscan2
- BCORL1 | c.2485C>T p.L829= | Silent (SNP) | VAF 28/120 reads (23%) | catalogued as rs764439741, COSV54390854; called by muse, mutect2, varscan2
- C3 | c.4218C>T p.S1406= | Silent (SNP) | VAF 20/109 reads (18%) | catalogued as COSV55569777; called by muse, mutect2, varscan2
- CACNA1A | c.1167C>T p.L389= | Silent (SNP) | VAF 19/94 reads (20%) | catalogued as COSV64191638; called by muse, mutect2, varscan2
- CARM1 | c.609C>T p.A203= | Silent (SNP) | VAF 68/316 reads (22%) | catalogued as rs998984299, COSV58999182; called by muse, varscan2
- CCDC141 | c.3384G>A p.P1128= | Silent (SNP) | VAF 19/57 reads (33%) | catalogued as rs754763045, COSV55369971; called by muse, mutect2, varscan2
- CCDC185 | c.483C>T p.F161= | Silent (SNP) | VAF 14/25 reads (56%) | catalogued as COSV64820420; called by muse, mutect2, varscan2
- CCT7 | c.69G>T p.V23= | Silent (SNP) | VAF 8/41 reads (20%) | catalogued as rs1308786064, COSV57821452; called by muse, mutect2, varscan2
- CCT8L2 | c.1452G>A p.G484= | Silent (SNP) | VAF 46/205 reads (22%) | catalogued as COSV63461763; called by muse, mutect2, varscan2
- CDC42BPB | c.3744C>T p.I1248= | Silent (SNP) | VAF 9/66 reads (14%) | catalogued as rs371401659; called by muse, mutect2, varscan2
- CDCP1 | c.2322C>T p.P774= | Silent (SNP) | VAF 29/123 reads (24%) | catalogued as COSV56104075; called by muse, mutect2, varscan2
- CDH22 | c.825C>T p.P275= | Silent (SNP) | VAF 22/124 reads (18%) | catalogued as COSV64836653; called by muse, mutect2, varscan2
- CDH6 | c.2145C>T p.F715= | Silent (SNP) | VAF 15/67 reads (22%) | catalogued as COSV54065375; called by muse, mutect2, varscan2
- CDHR5 | c.1461G>A p.T487= (on ENST00000358353 / NM_001171968.2; = p.T493= on NM_021924.5) | Silent (SNP) | VAF 12/44 reads (27%) | catalogued as rs375104662; called by muse, mutect2, varscan2
- CDK5RAP2 | c.105C>T p.P35= | Silent (SNP) | VAF 29/76 reads (38%) | catalogued as COSV62572450; called by muse, mutect2, varscan2
- CEL | c.999C>T p.I333= (on ENST00000673714; = p.I330= on NM_001807.6) | Silent (SNP) | VAF 8/53 reads (15%) | catalogued as rs1003013190, COSV100672291; called by muse, mutect2, varscan2
- CENPJ | c.513C>T p.L171= | Silent (SNP) | VAF 25/117 reads (21%) | catalogued as COSV67883078; called by muse, mutect2, varscan2
- CFAP61 | c.1314G>A p.V438= | Silent (SNP) | VAF 26/106 reads (25%) | catalogued as COSV55621225; called by muse, mutect2
- CFAP91 | c.693C>T p.L231= | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as rs569328619, COSV56339580; called by muse, mutect2, varscan2
- CHIA | c.378C>T p.F126= (on ENST00000343320; = p.F18= on NM_021797.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 94/180 reads (52%) | catalogued as COSV58473958; called by muse, mutect2, varscan2
- CILK1 | c.90C>T p.I30= | Silent (SNP) | VAF 42/157 reads (27%) | catalogued as rs765499188, COSV63153551; called by muse, mutect2, varscan2
- CLCN5 | c.957C>T p.L319= | Silent (SNP) | VAF 19/76 reads (25%) | catalogued as rs782167046, COSV56582245; called by muse, mutect2, varscan2
- CLEC3A | c.36G>A p.K12= (on ENST00000651443; = p.K3= on NM_005752.6) | Silent (SNP) | VAF 9/38 reads (24%) | catalogued as COSV55219969; called by muse, mutect2, varscan2
- CMTM7 | c.354C>T p.I118= | Silent (SNP) | VAF 29/142 reads (20%) | catalogued as rs994490887, COSV58550058; called by muse, mutect2, varscan2
- CPNE4 | c.1488G>A p.E496= | Silent (SNP) | VAF 27/109 reads (25%) | catalogued as rs555361257, COSV70190842; called by muse, mutect2, varscan2
- CPSF1 | c.3624G>A p.T1208= | Silent (SNP) | VAF 13/29 reads (45%) | catalogued as rs782030221, COSV58232443; called by muse, mutect2, varscan2
- CR1 | c.2673C>T p.P891= | Silent (SNP) | VAF 62/249 reads (25%) | catalogued as COSV65455704, COSV65456410; called by muse, mutect2, varscan2
- CSMD2 | c.420G>A p.G140= | Silent (SNP) | VAF 19/81 reads (23%) | catalogued as COSV53886209; called by muse, mutect2, varscan2
- DHCR7 | c.534C>T p.I178= | Silent (SNP) | VAF 19/80 reads (24%) | catalogued as rs1349721227, COSV62794587; ClinVar: likely benign; called by muse, mutect2, varscan2
- DNAH3 | c.4029C>T p.I1343= | Silent (SNP) | VAF 15/49 reads (31%) | catalogued as rs566800074, COSV54504639; called by muse, mutect2, varscan2
- DNAH3 | c.3696G>A p.Q1232= | Silent (SNP) | VAF 32/136 reads (24%) | catalogued as COSV54507350, COSV54515937; called by muse, mutect2, varscan2
- DNAJC2 | c.534C>T p.F178= | Silent (SNP) | VAF 11/79 reads (14%) | catalogued as COSV50789641; called by muse, mutect2, varscan2
- DPP10 | c.24C>T p.S8= | Silent (SNP) | VAF 16/63 reads (25%) | catalogued as COSV69741264; called by muse, mutect2, varscan2
- DPPA2 | c.102C>T p.D34= | Silent (SNP) | VAF 39/182 reads (21%) | catalogued as rs572153453, COSV72117901; called by muse, mutect2, varscan2
- DSG4 | c.195G>C p.S65= | Silent (SNP) | VAF 32/107 reads (30%) | catalogued as COSV100356338, COSV57389068; called by muse, mutect2, varscan2
- DYNC2H1 | c.7932G>A p.L2644= | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as COSV62088091; called by mutect2, varscan2
- DYSF | c.3786G>A p.R1262= | Silent (SNP) | VAF 40/157 reads (25%) | catalogued as COSV50274165; called by muse, mutect2, varscan2
- EN1 | c.423G>C p.R141= | Silent (SNP) | VAF 5/44 reads (11%) | catalogued as COSV54630414; called by mutect2, varscan2
- EPHA1 | c.1047C>T p.S349= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as COSV51969138; called by muse, mutect2
- ERAP1 | c.477C>T p.F159= | Silent (SNP) | VAF 23/119 reads (19%) | catalogued as COSV57085541; called by muse, mutect2, varscan2
- ERMAP | c.456C>T p.S152= | Silent (SNP) | VAF 36/122 reads (30%) | catalogued as COSV60273562; called by muse, mutect2, varscan2
- ERMARD | c.447C>A p.P149= | Silent (SNP) | VAF 31/117 reads (26%) | catalogued as COSV64649523; called by muse, mutect2, varscan2
- FAM83G | c.2148A>T p.G716= | Silent (SNP) | VAF 17/65 reads (26%) | catalogued as COSV58755801; called by muse, mutect2, varscan2
- FAT1 | c.13260C>T p.I4420= | Silent (SNP) | VAF 62/325 reads (19%) | catalogued as rs775490526, COSV71672329; called by muse, mutect2, varscan2
- FXYD1 | c.231G>A p.E77= | Silent (SNP) | VAF 16/101 reads (16%) | catalogued as rs1423632614, COSV54342173; called by muse, mutect2, varscan2
- GABRA5 | c.270G>A p.T90= | Silent (SNP) | VAF 15/60 reads (25%) | catalogued as rs1229491942, COSV59476432; called by muse, mutect2, varscan2
- GCN1 | c.2016C>T p.I672= | Silent (SNP) | VAF 17/77 reads (22%) | catalogued as COSV56104650; called by muse, mutect2, varscan2
- GIMAP8 | c.537C>T p.I179= | Silent (SNP) | VAF 48/160 reads (30%) | catalogued as rs1395325131, COSV56230102; called by muse, mutect2, varscan2
- GLRB | c.861C>T p.S287= | Silent (SNP) | VAF 30/86 reads (35%) | catalogued as rs1348835493, COSV52413864; called by muse, mutect2, varscan2
- GPAA1 | c.417C>T p.A139= | Silent (SNP) | VAF 14/60 reads (23%) | catalogued as rs1554763887, COSV100283984; called by muse, mutect2, varscan2
- GPRC5B | c.552C>T p.T184= | Silent (SNP) | VAF 12/97 reads (12%) | catalogued as rs780310222, COSV56025027, COSV56025426; called by muse, mutect2, varscan2
- GRB14 | c.1212C>T p.L404= | Silent (SNP) | VAF 29/159 reads (18%) | catalogued as rs147507583; called by muse, mutect2, varscan2
- GRIN2A | c.3909C>T p.D1303= | Silent (SNP) | VAF 35/129 reads (27%) | catalogued as rs765744766, COSV58023074; ClinVar: likely benign; called by muse, mutect2, varscan2
- GRIN2A | c.180G>A p.A60= | Silent (SNP) | VAF 24/114 reads (21%) | catalogued as COSV58023079; called by muse, mutect2, varscan2
- GRM4 | c.345C>T p.A115= | Silent (SNP) | VAF 9/32 reads (28%) | catalogued as COSV65211250; called by muse, mutect2, varscan2
- GRM6 | c.988C>T p.L330= | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as COSV51435371, COSV51450413; called by muse, mutect2, varscan2
- GTF2IRD2 | c.2328C>T p.I776= | Silent (SNP) | VAF 10/50 reads (20%) | catalogued as rs1380046187, COSV100736392; called by mutect2, varscan2
- GTF3C1 | c.2487G>A p.R829= | Silent (SNP) | VAF 8/46 reads (17%) | catalogued as COSV62239369; called by muse, mutect2, varscan2
- GUCA1C | c.498G>A p.L166= | Silent (SNP) | VAF 16/83 reads (19%) | catalogued as COSV53751656; called by muse, mutect2, varscan2
- H1-7 | c.663G>A p.V221= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as rs759572135, COSV58601752; called by muse, mutect2, varscan2
- HECTD4 | c.7260C>T p.I2420= | Silent (SNP) | VAF 22/108 reads (20%) | catalogued as rs771589029, COSV66387798, COSV66395716; called by muse, mutect2, varscan2
- HID1 | c.1164C>T p.F388= | Silent (SNP) | VAF 15/44 reads (34%) | catalogued as rs1262886212, COSV59351139; called by muse, mutect2, varscan2
- HLCS | c.747C>T p.S249= | Silent (SNP) | VAF 12/55 reads (22%) | catalogued as rs1188065092, COSV100358277, COSV60791694; called by muse, mutect2, varscan2
- HUWE1 | c.12207C>T p.I4069= | Silent (SNP) | VAF 30/84 reads (36%) | catalogued as COSV53336817; called by muse, mutect2, varscan2
- IFNE | c.171G>A p.R57= | Silent (SNP) | VAF 25/106 reads (24%) | catalogued as COSV58639507; called by muse, mutect2, varscan2
- IGSF1 | c.2592G>A p.V864= | Silent (SNP) | VAF 59/166 reads (36%) | catalogued as COSV63836440; called by muse, mutect2, varscan2
- IKZF1 | c.381C>T p.I127= | Silent (SNP) | VAF 7/53 reads (13%) | catalogued as rs1358802263, COSV58781979; called by muse, mutect2, varscan2
- IL13RA2 | c.9C>T p.F3= | Silent (SNP) | VAF 19/85 reads (22%) | catalogued as COSV54564006; called by muse, mutect2, varscan2
- IL1A | c.324C>T p.I108= | Silent (SNP) | VAF 22/116 reads (19%) | catalogued as COSV54519024; called by muse, mutect2, varscan2
- IL1R1 | c.1062C>T p.F354= | Silent (SNP) | VAF 22/73 reads (30%) | catalogued as COSV52104880; called by muse, varscan2
- IL1RAPL2 | c.1842C>T p.I614= | Silent (SNP) | VAF 24/107 reads (22%) | catalogued as COSV61145212; called by muse, mutect2, varscan2
- INMT | c.646C>T p.L216= | Silent (SNP) | VAF 24/90 reads (27%) | catalogued as COSV50000353; called by muse, mutect2, varscan2
- INPPL1 | c.2922C>T p.A974= | Silent (SNP) | VAF 40/155 reads (26%) | catalogued as rs200100388, COSV53353743; called by muse, mutect2, varscan2
- IP6K2 | c.331C>T p.L111= | Silent (SNP) | VAF 59/267 reads (22%) | catalogued as COSV100151739; called by muse, mutect2, varscan2
- IP6K2 | c.330C>T p.L110= | Silent (SNP) | VAF 59/265 reads (22%) | catalogued as rs1243512637, COSV100151742; called by muse, mutect2, varscan2
- IRGC | c.825C>T p.G275= | Silent (SNP) | VAF 23/81 reads (28%) | catalogued as rs755683247, COSV54983108; called by muse, mutect2, varscan2
- KANSL1L | c.1581C>T p.S527= | Silent (SNP) | VAF 8/53 reads (15%) | catalogued as COSV55990043; called by muse, mutect2, varscan2
- KAZALD1 | c.255C>T p.L85= | Silent (SNP) | VAF 9/36 reads (25%) | catalogued as COSV64630025; called by muse, mutect2, varscan2
- KCNA6 | c.351C>T p.F117= | Silent (SNP) | VAF 26/101 reads (26%) | catalogued as rs1161020106, COSV54974317; called by muse, mutect2, varscan2
- KCNH1 | c.1899G>A p.E633= (on ENST00000271751 / NM_172362.3; = p.E606= on NM_002238.4) | Silent (SNP) | VAF 60/135 reads (44%) | catalogued as COSV55071802; called by muse, mutect2, varscan2
- KDM1A | c.816C>T p.P272= | Silent (SNP) | VAF 80/188 reads (43%) | catalogued as rs751093595, COSV100752421; called by muse, mutect2, varscan2
- KDM1A | c.817C>T p.L273= | Silent (SNP) | VAF 77/181 reads (43%) | catalogued as rs754447616, COSV100752425; called by muse, mutect2, varscan2
- KIF27 | c.916C>T p.L306= | Silent (SNP) | VAF 24/105 reads (23%) | catalogued as rs1254876416, COSV52825780; called by muse, mutect2, varscan2
- KLK14 | c.510C>T p.S170= | Silent (SNP) | VAF 59/230 reads (26%) | catalogued as COSV50067999; called by muse, mutect2, varscan2
- KMT2D | c.15975C>T p.P5325= | Silent (SNP) | VAF 11/29 reads (38%) | catalogued as rs780850935, COSV56416697; called by muse, mutect2, varscan2
- LAMA1 | c.8082C>T p.P2694= | Silent (SNP) | VAF 15/81 reads (19%) | catalogued as COSV67533041; called by muse, mutect2, varscan2
- LAMB4 | c.1806C>T p.L602= | Silent (SNP) | VAF 15/69 reads (22%) | catalogued as rs778882872, COSV52714699; called by muse, mutect2, varscan2
- LIPN | c.649C>T p.L217= | Silent (SNP) | VAF 15/74 reads (20%) | catalogued as rs548239086, COSV104433723, COSV68383758; called by muse, mutect2, varscan2
- LRP2 | c.7623C>T p.F2541= | Silent (SNP) | VAF 40/110 reads (36%) | catalogued as COSV55543632; called by muse, mutect2, varscan2
- LZTS1 | c.1053C>T p.S351= | Silent (SNP) | VAF 24/59 reads (41%) | catalogued as COSV56115982; called by muse, mutect2, varscan2
- MACF1 | c.4101C>T p.S1367= | Silent (SNP) | VAF 30/147 reads (20%) | catalogued as COSV100483048; called by muse, mutect2, varscan2
- MAPK11 | c.579C>T p.I193= | Silent (SNP) | VAF 9/50 reads (18%) | catalogued as COSV57996513; called by muse, mutect2, varscan2
- MAPK6 | c.1194C>T p.P398= | Silent (SNP) | VAF 28/110 reads (25%) | catalogued as COSV99958966; called by muse, mutect2, varscan2
- MC5R | c.972G>A p.R324= | Silent (SNP) | VAF 16/95 reads (17%) | catalogued as COSV61254056; called by muse, mutect2, varscan2
- MED8 | c.240G>C p.V80= | Silent (SNP) | VAF 37/65 reads (57%) | catalogued as COSV51939837; called by muse, mutect2, varscan2
- MEIOC | c.864C>T p.Y288= | Silent (SNP) | VAF 13/49 reads (27%) | catalogued as rs1022675033, COSV63439512; called by muse, mutect2, varscan2
- MGA | c.4854T>A p.I1618= | Silent (SNP) | VAF 25/124 reads (20%) | catalogued as COSV54949931; called by muse, mutect2, varscan2
- MGAM | c.3774G>A p.E1258= | Silent (SNP) | VAF 62/276 reads (22%) | catalogued as COSV72073870; called by muse, mutect2, varscan2
- MGAM | c.4962C>T p.F1654= | Silent (SNP) | VAF 13/78 reads (17%) | catalogued as COSV72073872; called by muse, mutect2, varscan2
- MICAL3 | c.5937C>T p.L1979= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as rs372566077, COSV52811072; called by muse, mutect2
- MPZL2 | c.537G>A p.R179= | Silent (SNP) | VAF 77/347 reads (22%) | catalogued as COSV54048406; called by muse, mutect2, varscan2
- MSI1 | c.684C>T p.A228= | Silent (SNP) | VAF 29/127 reads (23%) | catalogued as COSV57455498; called by muse, mutect2, varscan2
- MUC2 | c.2040C>T p.S680= | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as rs1449205980; called by muse, mutect2, varscan2
- MYH2 | c.1071G>A p.G357= | Silent (SNP) | VAF 55/234 reads (24%) | catalogued as COSV55432900; called by muse, mutect2, varscan2
- MYH6 | c.474C>T p.S158= | Silent (SNP) | VAF 67/208 reads (32%) | catalogued as rs755939165, COSV62448353; called by muse, mutect2, varscan2
- MYO18B | c.963C>T p.F321= | Silent (SNP) | VAF 5/28 reads (18%) | catalogued as rs1353802786, COSV59127364; called by muse, mutect2
- NBEAL2 | c.3093C>T p.T1031= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as COSV99434867; called by muse, mutect2
- NBPF11 | c.1671C>T p.P557= | Silent (SNP) | VAF 35/304 reads (12%) | catalogued as rs1302595060; called by muse, mutect2, varscan2
- NCAPD3 | c.3015C>T p.L1005= | Silent (SNP) | VAF 22/84 reads (26%) | catalogued as rs1245391109, COSV73244838; called by muse, mutect2, varscan2
- NEFH | c.984G>A p.R328= | Silent (SNP) | VAF 36/156 reads (23%) | catalogued as rs1482037030, COSV60215566; called by muse, mutect2, varscan2
- NNT | c.244T>C p.L82= | Silent (SNP) | VAF 54/225 reads (24%) | catalogued as COSV52923060; called by muse, mutect2, varscan2
- NOTCH3 | c.5733C>T p.I1911= | Silent (SNP) | VAF 12/54 reads (22%) | catalogued as COSV54628118; called by muse, mutect2, varscan2
- NUB1 | c.1509C>T p.S503= (on ENST00000568733 / NM_001243351.1; = p.S489= on NM_016118.4) | Silent (SNP) | VAF 44/221 reads (20%) | catalogued as rs993424054, COSV63425990; called by muse, mutect2, varscan2
- OGDH | c.309C>T p.S103= | Silent (SNP) | VAF 31/142 reads (22%) | catalogued as COSV56046257; called by muse, mutect2, varscan2
- OR10G4 | c.87C>T p.F29= | Silent (SNP) | VAF 33/116 reads (28%) | catalogued as COSV57976857; called by muse, mutect2, varscan2
- OR1A2 | c.81C>T p.F27= | Silent (SNP) | VAF 41/162 reads (25%) | catalogued as COSV67936176; called by muse, mutect2, varscan2
- OR51V1 | c.462G>A p.R154= | Silent (SNP) | VAF 22/118 reads (19%) | catalogued as rs867904279, COSV58314319; called by muse, mutect2, varscan2
- OR52E4 | c.276A>G p.Q92= | Silent (SNP) | VAF 28/134 reads (21%) | catalogued as rs547145216, COSV57624086; called by muse, mutect2, varscan2
- OR5AS1 | c.432C>T p.F144= | Silent (SNP) | VAF 41/198 reads (21%) | catalogued as COSV57981012; called by muse, mutect2, varscan2
- OR5D13 | c.369C>T p.D123= | Silent (SNP) | VAF 43/227 reads (19%) | catalogued as rs766341159, COSV62332929; called by muse, mutect2, varscan2
- OR5D18 | c.598C>T p.L200= | Silent (SNP) | VAF 30/146 reads (21%) | catalogued as COSV61736404; called by muse, mutect2, varscan2
- OR7D4 | c.135C>T p.I45= | Silent (SNP) | VAF 29/150 reads (19%) | catalogued as COSV58071237; called by muse, mutect2, varscan2
- OR8B3 | c.910C>T p.L304= | Silent (SNP) | VAF 26/122 reads (21%) | catalogued as COSV63541341; called by muse, mutect2, varscan2
- ORAI2 | c.561C>T p.G187= | Silent (SNP) | VAF 14/85 reads (16%) | catalogued as COSV62689262; called by muse, mutect2, varscan2
- P2RY12 | c.732A>T p.V244= | Silent (SNP) | VAF 31/89 reads (35%) | catalogued as COSV56370678; called by muse, mutect2, varscan2
- PAAF1 | c.537C>T p.I179= | Silent (SNP) | VAF 23/93 reads (25%) | catalogued as COSV60154686; called by muse, mutect2, varscan2
- PADI4 | c.1020G>A p.E340= | Silent (SNP) | VAF 23/58 reads (40%) | catalogued as COSV64923158; called by muse, mutect2, varscan2
- PAPPA | c.3624C>T p.F1208= | Silent (SNP) | VAF 35/164 reads (21%) | catalogued as rs202244318, COSV60278544; called by muse, mutect2, varscan2
- PAPPA | c.3960G>A p.L1320= | Silent (SNP) | VAF 21/75 reads (28%) | catalogued as COSV60278549; called by muse, mutect2, varscan2
- PAX4 | c.409C>T p.L137= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as COSV58387755; called by muse, mutect2, varscan2
- PCDHB13 | c.345C>T p.F115= | Silent (SNP) | VAF 21/118 reads (18%) | catalogued as COSV53392971; called by muse, mutect2, varscan2
- PCDHGA8 | c.2313C>T p.P771= | Silent (SNP) | VAF 19/114 reads (17%) | catalogued as COSV53909371; called by muse, mutect2, varscan2
- PDE8A | c.1980G>T p.G660= | Silent (SNP) | VAF 17/99 reads (17%) | catalogued as COSV59635170; called by muse, mutect2, varscan2
- PDLIM4 | c.660C>T p.A220= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as rs1340790859, COSV53803512; called by muse, mutect2, varscan2
- PIP5K1B | c.1230G>A p.R410= | Silent (SNP) | VAF 16/74 reads (22%) | catalogued as rs890581895, COSV55242482; called by muse, mutect2
- PIWIL4 | c.963G>A p.K321= | Silent (SNP) | VAF 24/108 reads (22%) | catalogued as COSV54408101; called by muse, mutect2, varscan2
- PLA2G12B | c.453C>T p.V151= | Silent (SNP) | VAF 30/127 reads (24%) | catalogued as rs958003862, COSV65978305; called by muse, mutect2, varscan2
- PLEC | c.10140G>T p.V3380= (on ENST00000322810 / NM_201380.4; = p.V3270= on NM_000445.5) | Silent (SNP) | VAF 40/102 reads (39%) | catalogued as COSV59609752; called by muse, mutect2, varscan2
- PNKD | c.381C>T p.L127= | Silent (SNP) | VAF 20/75 reads (27%) | catalogued as COSV51231136; called by muse, mutect2, varscan2
- PNLDC1 | c.1413C>T p.I471= | Silent (SNP) | VAF 13/61 reads (21%) | catalogued as COSV51704065; called by muse, mutect2, varscan2
- POLL | c.1215C>T p.A405= | Silent (SNP) | VAF 14/75 reads (19%) | catalogued as COSV54573750; called by muse, mutect2, varscan2
- POLR2A | c.1260C>T p.I420= | Silent (SNP) | VAF 20/85 reads (24%) | catalogued as rs1288521146, COSV59489930; called by muse, mutect2, varscan2
- PPME1 | c.423C>T p.A141= | Silent (SNP) | VAF 30/166 reads (18%) | catalogued as COSV60295823; called by muse, mutect2, varscan2
- PPP1R1B | c.198G>A p.S66= | Silent (SNP) | VAF 21/95 reads (22%) | catalogued as rs773467666, COSV54201616; called by muse, mutect2, varscan2
- PRKCB | c.765C>T p.F255= | Silent (SNP) | VAF 23/116 reads (20%) | catalogued as COSV57769044; called by muse, mutect2, varscan2
- PROKR2 | c.411C>T p.V137= | Silent (SNP) | VAF 10/49 reads (20%) | catalogued as COSV54085552; called by muse, mutect2, varscan2
- PTDSS2 | c.879C>T p.F293= | Silent (SNP) | VAF 9/43 reads (21%) | catalogued as COSV57277154; called by muse, mutect2, varscan2
- PTH2R | c.1368G>A p.T456= | Silent (SNP) | VAF 12/51 reads (24%) | catalogued as rs193022380; called by muse, mutect2, varscan2
- PTPRO | c.3159C>T p.F1053= (on ENST00000281171 / NM_030667.3; = p.F1025= on NM_002848.4) | Silent (SNP) | VAF 20/108 reads (19%) | catalogued as rs139672715, COSV55504599; called by muse, mutect2, varscan2
- RFX2 | c.432C>T p.I144= | Silent (SNP) | VAF 12/39 reads (31%) | catalogued as rs1417246040, COSV57939624; called by muse, mutect2, varscan2
- RPL6 | c.318G>A p.V106= | Silent (SNP) | VAF 13/90 reads (14%) | catalogued as rs1401465027, COSV99176114; called by muse, mutect2, varscan2
- RTL3 | c.924C>T p.F308= | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as COSV58183099; called by muse, mutect2
- SCN3A | c.354G>A p.R118= | Silent (SNP) | VAF 15/59 reads (25%) | catalogued as COSV51803142; called by muse, mutect2, varscan2
- SEC14L2 | c.969G>A p.K323= | Silent (SNP) | VAF 13/73 reads (18%) | catalogued as COSV57240298; called by muse, mutect2, varscan2
- SEC24B | c.2451C>T p.S817= | Silent (SNP) | VAF 15/57 reads (26%) | catalogued as COSV54496192; called by muse, mutect2, varscan2
- SERPINA12 | c.555C>T p.T185= | Silent (SNP) | VAF 42/158 reads (27%) | catalogued as COSV57942546, COSV57945061; called by muse, mutect2, varscan2
- SFRP2 | c.738C>T p.T246= | Silent (SNP) | VAF 19/96 reads (20%) | catalogued as COSV56836937; called by muse, mutect2, varscan2
- SIRT5 | c.471C>T p.I157= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as COSV63079841; called by muse, mutect2
- SLC2A9 | c.741G>A p.L247= | Silent (SNP) | VAF 13/44 reads (30%) | catalogued as rs1436607124, COSV53317363; called by muse, mutect2, varscan2
- SLC47A1 | c.1260C>T p.G420= | Silent (SNP) | VAF 47/224 reads (21%) | catalogued as COSV54499349; called by muse, mutect2, varscan2
- SLC5A2 | c.495C>T p.F165= | Silent (SNP) | VAF 16/82 reads (20%) | catalogued as rs775073955, COSV57890357; called by muse, mutect2, varscan2
- SLC5A7 | c.405G>A p.L135= | Silent (SNP) | VAF 30/85 reads (35%) | catalogued as COSV50889328, COSV99887254; called by muse, mutect2, varscan2
- SLITRK4 | c.2127C>T p.F709= | Silent (SNP) | VAF 46/141 reads (33%) | catalogued as rs782468238, COSV62022453; called by muse, mutect2, varscan2
- SMARCA4 | c.1386C>T p.I462= | Silent (SNP) | VAF 3/18 reads (17%) | catalogued as rs1265247876, COSV60788585; ClinVar: likely benign; called by muse, mutect2
- SMARCB1 | c.684C>T p.S228= (on ENST00000263121; = p.S274= on NM_003073.5) | Silent (SNP) | VAF 30/118 reads (25%) | catalogued as rs1386414055, COSV54094236; called by muse, mutect2, varscan2
- SPAM1 | c.495G>A p.K165= | Silent (SNP) | VAF 20/105 reads (19%) | catalogued as COSV56141465, COSV56142010; called by muse, mutect2, varscan2
- SPATA31D1 | c.4563G>A p.R1521= | Silent (SNP) | VAF 5/31 reads (16%) | catalogued as rs1295811704, COSV61193403; called by muse, mutect2, varscan2
- SPRR2D | c.90G>A p.P30= | Silent (SNP) | VAF 40/180 reads (22%) | catalogued as rs756954313, COSV64209055; called by muse, mutect2, varscan2
- SRCAP | c.5664C>T p.S1888= | Silent (SNP) | VAF 18/132 reads (14%) | catalogued as rs997553542, COSV99349525; called by muse, mutect2, varscan2
- STARD13 | c.381G>A p.R127= (on ENST00000336934 / NM_001243476.3; = p.R9= on NM_052851.3) | Silent (SNP) | VAF 16/89 reads (18%) | catalogued as COSV55227940; called by muse, mutect2, varscan2
- STARD4 | c.537G>A p.G179= | Silent (SNP) | VAF 32/157 reads (20%) | catalogued as rs534000242, COSV56967417; called by muse, mutect2, varscan2
- STATH | c.9C>T p.F3= | Silent (SNP) | VAF 24/92 reads (26%) | catalogued as rs144461948, COSV55893463; called by muse, mutect2, varscan2
- STXBP5L | c.1863A>G p.P621= | Silent (SNP) | VAF 11/57 reads (19%) | catalogued as COSV56502735, COSV56504192; called by muse, mutect2, varscan2
- TAP2 | c.465C>T p.A155= | Silent (SNP) | VAF 18/84 reads (21%) | catalogued as COSV66487581; called by muse, mutect2, varscan2
- TAT | c.1299G>A p.R433= | Silent (SNP) | VAF 14/67 reads (21%) | catalogued as COSV100587447, COSV100587553; called by muse, mutect2, varscan2
- TM9SF4 | c.912C>T p.T304= | Silent (SNP) | VAF 8/46 reads (17%) | catalogued as COSV54104932; called by muse, mutect2, varscan2
- TMED3 | c.645C>T p.V215= | Silent (SNP) | VAF 15/98 reads (15%) | catalogued as rs376038327; called by muse, mutect2, varscan2
- TNR | c.1071C>T p.I357= | Silent (SNP) | VAF 50/113 reads (44%) | catalogued as COSV54873055, COSV54873734; called by muse, mutect2, varscan2
- TNS4 | c.957C>T p.S319= | Silent (SNP) | VAF 16/62 reads (26%) | catalogued as COSV54183688; called by muse, varscan2
- TOX | c.1557G>A p.R519= | Silent (SNP) | VAF 13/80 reads (16%) | catalogued as COSV100812973, COSV63843244; called by muse, mutect2, varscan2
- TOX | c.1347C>T p.L449= | Silent (SNP) | VAF 15/77 reads (19%) | catalogued as COSV63266214; called by muse, mutect2, varscan2
- TRAFD1 | c.300C>T p.L100= | Silent (SNP) | VAF 28/116 reads (24%) | catalogued as COSV57503571, COSV99987004; called by muse, mutect2, varscan2
- TRAV26-2 | c.30C>T p.L10= | Silent (SNP) | VAF 10/45 reads (22%) | catalogued as rs1289823683; called by muse, mutect2, varscan2
- TRAV9-2 | c.285G>A p.E95= | Silent (SNP) | VAF 15/80 reads (19%) | called by muse, mutect2, varscan2
- TRDV1 | c.201C>T p.F67= | Silent (SNP) | VAF 33/122 reads (27%) | called by muse, mutect2, varscan2
- TRIM69 | c.612C>T p.S204= (on ENST00000329464 / NM_182985.5; = p.S45= on NM_080745.5) | Silent (SNP) | VAF 17/62 reads (27%) | catalogued as COSV57803057; called by muse, mutect2, varscan2
- TRPC7 | c.363C>T p.I121= | Silent (SNP) | VAF 16/62 reads (26%) | catalogued as COSV61453869; called by muse, mutect2, varscan2
- TRPM2 | c.2139G>A p.G713= | Silent (SNP) | VAF 14/61 reads (23%) | catalogued as rs775121487, COSV55966816; called by muse, mutect2, varscan2
- TSC2 | c.2901G>A p.K967= | Silent (SNP) | VAF 32/107 reads (30%) | catalogued as COSV54757802; called by muse, mutect2, varscan2
- UBQLNL | c.264G>A p.R88= | Silent (SNP) | VAF 8/93 reads (9%) | catalogued as COSV100973984; called by muse, mutect2
- UHRF1BP1 | c.1641C>T p.L547= | Silent (SNP) | VAF 43/148 reads (29%) | catalogued as COSV51953163; called by muse, mutect2, varscan2
- UNC79 | c.531G>A p.T177= | Silent (SNP) | VAF 15/94 reads (16%) | catalogued as rs749178515, COSV99826314; called by muse, mutect2, varscan2
- XDH | c.1189C>T p.L397= | Silent (SNP) | VAF 24/115 reads (21%) | catalogued as rs1407513623, COSV65147300; called by muse, mutect2, varscan2
- XKR6 | c.1893C>T p.L631= | Silent (SNP) | VAF 50/125 reads (40%) | catalogued as COSV58654734; called by muse, mutect2, varscan2
- ZBED9 | c.2172G>A p.G724= | Silent (SNP) | VAF 14/44 reads (32%) | catalogued as COSV71729215; called by muse, mutect2, varscan2
- ZBTB21 | c.621T>C p.S207= | Silent (SNP) | VAF 39/180 reads (22%) | catalogued as COSV60403317; called by muse, mutect2, varscan2
- ZBTB45 | c.298C>T p.L100= | Silent (SNP) | VAF 11/96 reads (11%) | catalogued as COSV63523345; called by muse, mutect2, varscan2
- ZIM3 | c.534A>G p.S178= | Silent (SNP) | VAF 51/219 reads (23%) | catalogued as COSV54140566; called by muse, mutect2, varscan2
- ZMYND15 | c.1317C>T p.L439= | Silent (SNP) | VAF 12/47 reads (26%) | catalogued as COSV52640160; called by muse, mutect2, varscan2
- ZNF558 | c.957C>T p.P319= | Silent (SNP) | VAF 27/107 reads (25%) | catalogued as rs1200193887, COSV100037812, COSV56862476; called by muse, mutect2, varscan2
- ZNF560 | c.873C>T p.S291= | Silent (SNP) | VAF 37/148 reads (25%) | catalogued as COSV56866204; called by muse, mutect2, varscan2
- ZNF646 | c.3537G>A p.G1179= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as COSV54922952; called by muse, mutect2
- ZNF682 | c.795C>T p.A265= | Silent (SNP) | VAF 22/106 reads (21%) | catalogued as rs913425373, COSV62066263; called by muse, mutect2, varscan2
- A1CF | c.100-6602G>A | Intron (SNP) | VAF 28/178 reads (16%) | catalogued as rs766003757, COSV99255444; called by muse, mutect2, varscan2
- ABCA3 | c.-44C>T | 5'UTR (SNP) | VAF 7/22 reads (32%) | catalogued as COSV100068137; called by muse, mutect2, varscan2
- AC058822.1 | c.1018-288278C>T | Intron (SNP) | VAF 12/68 reads (18%) | called by mutect2, varscan2
- AL132655.6 | chr20:58840628 C>T | 5'Flank (SNP) | VAF 6/28 reads (21%) | catalogued as rs1305983628, COSV58329191; called by muse, mutect2
- AL353804.7 | chrX:73846513 G>A | 5'Flank (SNP) | VAF 38/126 reads (30%) | called by muse, mutect2, varscan2
- ATP6AP1L | n.1679C>T | RNA (SNP) | VAF 22/85 reads (26%) | catalogued as COSV104430734, COSV66474501; called by muse, mutect2, varscan2
- CFAP47 | c.5536-588C>T | Intron (SNP) | VAF 20/57 reads (35%) | catalogued as COSV57971739; called by muse, mutect2, varscan2
- IFRD2 | c.-60C>T | 5'UTR (SNP) | VAF 11/51 reads (22%) | catalogued as COSV57112827; called by muse, mutect2, varscan2
- LINC01098 | n.720G>A | RNA (SNP) | VAF 35/154 reads (23%) | called by muse, mutect2, varscan2
- LYVE1 | c.-1G>A | 5'UTR (SNP) | VAF 7/47 reads (15%) | catalogued as rs766130151, COSV99810972; called by muse, mutect2
- MIR133A2 | n.21G>A | RNA (SNP) | VAF 4/13 reads (31%) | called by muse, mutect2, varscan2
- NACA | c.70+3497C>T | Intron (SNP) | VAF 23/124 reads (19%) | catalogued as rs372575337; called by muse, mutect2, varscan2
- OR3A4P | n.1062C>T | RNA (SNP) | VAF 33/112 reads (29%) | catalogued as rs981026621; called by muse, mutect2, varscan2
- RPL26P30 | n.817T>G | RNA (SNP) | VAF 31/181 reads (17%) | called by muse, mutect2, varscan2
- SLC22A17 | n.1127C>T | RNA (SNP) | VAF 19/92 reads (21%) | catalogued as rs531132605, COSV52834884; called by muse, mutect2, varscan2
- SLC22A17 | n.1126C>T | RNA (SNP) | VAF 18/92 reads (20%) | catalogued as COSV99248592; called by muse, mutect2, varscan2
- SLC5A1 | chr22:32039878 G>A | 5'Flank (SNP) | VAF 28/114 reads (25%) | called by muse, mutect2, varscan2
- ZPLD1 | c.-160G>A | 5'UTR (SNP) | VAF 19/89 reads (21%) | catalogued as COSV60352212; called by muse, mutect2, varscan2
